Somatic mutation profile of tumor specimen C3L-08311-02 (aliquot CPT0478000006) from CPTAC case C3L-08311, project CPTAC-3 (Stomach — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Stomach, NOS; AJCC pathologic stage: Stage IIA; Tumor grade: G2; Age at diagnosis: 77.6 years (28,351 days).
Specimen C3L-08311-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Antrum; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2e3badea-2c39-4da5-8647-c57b1a19f292.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-08311-31 (Blood Derived Normal), aliquot CPT0475780003; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/466b900a-8712-4fa7-aca0-27e7ac9bc315

The open-access MAF lists 718 somatic variants for this specimen: 506 protein-altering or splice-affecting, 190 silent, 22 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 473, Silent 190, Nonsense Mutation 19, Intron 12, Frame Shift Del 6, Splice Site 4, 3'UTR 4, 5'Flank 3, Splice Region 3, 3'Flank 1, RNA 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCB1 | c.3194C>T p.T1065M | Missense Mutation (SNP) | VAF 32/446 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs776877163, COSV55946264; called by muse, mutect2
- ADAMTS10 | c.3076C>T p.R1026C | Missense Mutation (SNP) | VAF 17/343 reads (5%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.748); catalogued as rs1555736475; called by muse, mutect2
- ADAMTS14 | c.62C>T p.A21V | Missense Mutation (SNP) | VAF 31/400 reads (8%) | SIFT tolerated (0.23); PolyPhen benign (0.025); catalogued as rs760571652; called by muse, mutect2
- ADAMTS20 | c.3709T>C p.Y1237H | Missense Mutation (SNP) | VAF 18/272 reads (7%) | SIFT tolerated (0.11); PolyPhen benign (0.059); catalogued as COSV101166098; called by muse, mutect2
- AKAP12 | c.2689G>A p.A897T | Missense Mutation (SNP) | VAF 31/442 reads (7%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as rs746212006, COSV53577292; called by muse, mutect2
- ALMS1 | c.5317T>A p.L1773M | Missense Mutation (SNP) | VAF 14/334 reads (4%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.973); catalogued as rs1284668495; called by muse, mutect2
- ANKS1B | c.607C>T p.R203C | Missense Mutation (SNP) | VAF 14/376 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1269579871, COSV61345301; called by muse, mutect2
- APOA4 | c.814G>A p.E272K | Missense Mutation (SNP) | VAF 24/473 reads (5%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.46); catalogued as rs1366912241; called by muse, mutect2
- AQR | c.3862C>T p.R1288C | Missense Mutation (SNP) | VAF 13/224 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV50044610; called by muse, mutect2
- ATP9A | c.793G>A p.A265T | Missense Mutation (SNP) | VAF 18/286 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.957); catalogued as rs751286712, COSV58762861; called by muse, mutect2
- AWAT2 | c.799A>G p.K267E | Missense Mutation (SNP) | VAF 16/408 reads (4%) | SIFT tolerated (0.84); PolyPhen benign (0.005); catalogued as rs1298624871; called by muse, mutect2
- B3GALT4 | c.697C>T p.R233C | Missense Mutation (SNP) | VAF 22/537 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.058); catalogued as COSV65851885; called by muse, mutect2
- BICDL1 | c.1308G>A p.T436= | Splice Region (SNP) | VAF 9/178 reads (5%) | catalogued as rs1033869619; called by muse, mutect2
- C1orf127 | c.1444C>A p.L482I | Missense Mutation (SNP) | VAF 18/385 reads (5%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.979); catalogued as COSV65436500; called by muse, mutect2
- C3 | c.2641C>T p.R881C | Missense Mutation (SNP) | VAF 16/396 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.907); catalogued as rs1199323072, COSV55579919; called by muse, mutect2
- CAPN5 | c.454G>A p.E152K (on ENST00000456580; = p.E112K on NM_004055.5) | Missense Mutation (SNP) | VAF 12/298 reads (4%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as rs782738219, COSV53685788; called by muse, mutect2
- CASK | c.46G>T p.E16* | Nonsense Mutation (SNP) | VAF 25/390 reads (6%) | catalogued as COSV100587814; called by muse, mutect2
- CCDC65 | c.871C>T p.R291W | Missense Mutation (SNP) | VAF 20/376 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.721); catalogued as rs1371441762; called by muse, mutect2
- CCDC77 | c.1372C>T p.R458C | Missense Mutation (SNP) | VAF 38/368 reads (10%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.915); catalogued as rs1467629558; called by muse, mutect2, varscan2
- CCNQ | c.625G>A p.A209T | Missense Mutation (SNP) | VAF 20/406 reads (5%) | SIFT tolerated (0.39); PolyPhen benign (0.089); catalogued as rs1557026001; called by muse, mutect2
- CDC42BPG | c.4486G>A p.E1496K | Missense Mutation (SNP) | VAF 12/359 reads (3%) | SIFT tolerated (0.09); PolyPhen benign (0.001); catalogued as rs1210379157, COSV61347475; called by muse, mutect2
- CDYL | c.1541C>T p.A514V (on ENST00000328908 / NM_001368125.1; = p.A460V on NM_004824.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 22/410 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.98); catalogued as COSV59359552; called by muse, mutect2
- CEACAM18 | c.1036C>T p.R346C | Missense Mutation (SNP) | VAF 14/351 reads (4%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.833); catalogued as rs912258200, COSV101140396; called by muse, mutect2
- CEP126 | c.2193del p.E732Kfs*25 | Frame Shift Del (DEL) | VAF 22/251 reads (9%) | catalogued as rs755857306; called by mutect2, pindel
- CGN | c.166C>T p.R56C | Missense Mutation (SNP) | VAF 21/426 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1006810957, COSV99642139; called by muse, mutect2
- CHAT | c.1712G>T p.R571I | Missense Mutation (SNP) | VAF 22/349 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100339456, COSV60328097; called by muse, mutect2
- CHSY3 | c.224C>T p.S75L | Missense Mutation (SNP) | VAF 24/418 reads (6%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.028); catalogued as rs1326987084; called by muse, mutect2
- CLUH | c.3389C>T p.A1130V (on ENST00000435359; = p.A1169V on NM_015229.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 18/312 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1368091556, COSV70928015; called by muse, mutect2
- COL18A1 | c.5095C>T p.R1699C (on ENST00000359759 / NM_130444.3; = p.R1464C on NM_030582.4) | Missense Mutation (SNP) | VAF 20/454 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as rs1261107453; called by muse, mutect2
- COPS5 | c.386G>A p.R129H | Missense Mutation (SNP) | VAF 14/230 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs889246427, COSV63474621; called by muse, mutect2
- CPSF1 | c.3632A>G p.Y1211C | Missense Mutation (SNP) | VAF 14/354 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1564683969; called by muse, mutect2
- CPSF1 | c.1993G>A p.V665I | Missense Mutation (SNP) | VAF 22/426 reads (5%) | SIFT tolerated (0.46); PolyPhen benign (0.241); catalogued as rs782058845, COSV58235024; called by muse, mutect2
- CPZ | c.613G>T p.A205S (on ENST00000360986 / NM_001014447.3; = p.A194S on NM_003652.3) | Missense Mutation (SNP) | VAF 20/466 reads (4%) | SIFT tolerated (0.72); PolyPhen benign (0.015); catalogued as COSV59922276; called by muse, mutect2
- CUBN | c.5693A>G p.D1898G | Missense Mutation (SNP) | VAF 18/270 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.883); catalogued as COSV64721616; called by muse, mutect2
- CYFIP1 | c.1316C>T p.T439M | Missense Mutation (SNP) | VAF 26/508 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.768); catalogued as rs1182995430; called by muse, mutect2
- DAXX | c.661G>A p.A221T | Missense Mutation (SNP) | VAF 22/522 reads (4%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs776375824, COSV56473739; called by muse, mutect2
- DCP1B | c.1441G>A p.A481T | Missense Mutation (SNP) | VAF 33/309 reads (11%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs186204171; called by muse, mutect2, varscan2
- DHH | c.851G>A p.G284D | Missense Mutation (SNP) | VAF 24/448 reads (5%) | SIFT tolerated (0.44); PolyPhen benign (0.114); catalogued as rs1261908521; called by muse, mutect2
- DLG5 | c.4147G>A p.A1383T | Missense Mutation (SNP) | VAF 30/456 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1338661135; called by muse, mutect2
- DLGAP1 | c.1873G>A p.V625I | Missense Mutation (SNP) | VAF 17/427 reads (4%) | SIFT tolerated (0.61); PolyPhen benign (0.003); catalogued as rs956162482, COSV59840596; called by muse, mutect2
- DNAH1 | c.11891C>T p.A3964V | Missense Mutation (SNP) | VAF 27/359 reads (8%) | SIFT tolerated (0.14); PolyPhen benign (0.039); catalogued as COSV56235135; called by muse, mutect2
- DOCK10 | c.122G>A p.R41Q | Missense Mutation (SNP) | VAF 14/244 reads (6%) | SIFT tolerated (0.35); PolyPhen benign (0.043); catalogued as rs938780738; called by muse, mutect2
- ECEL1 | c.727G>A p.A243T | Missense Mutation (SNP) | VAF 16/368 reads (4%) | SIFT tolerated (0.16); PolyPhen benign (0.355); catalogued as rs1319472137, COSV58812116; called by muse, mutect2
- EEF2 | c.1471G>A p.A491T | Missense Mutation (SNP) | VAF 16/387 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.041); catalogued as COSV58579604; called by muse, mutect2
- EIF3G | c.550G>A p.E184K | Missense Mutation (SNP) | VAF 28/354 reads (8%) | SIFT tolerated (0.31); PolyPhen benign (0.015); catalogued as rs1315028177, COSV53458560; called by muse, mutect2
- EIF3H | c.313C>T p.R105W | Missense Mutation (SNP) | VAF 16/211 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV52666034; called by muse, mutect2
- ELAVL1 | c.829C>T p.R277C | Missense Mutation (SNP) | VAF 22/374 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.431); catalogued as COSV100688229; called by muse, mutect2
- EPPK1 | c.3598C>T p.R1200W | Missense Mutation (SNP) | VAF 20/523 reads (4%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.917); catalogued as rs782015228, COSV73261477; called by muse, mutect2
- FAM171A2 | c.1939G>A p.V647M | Missense Mutation (SNP) | VAF 14/344 reads (4%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as rs1322505812; called by muse, mutect2
- FBXO31 | c.884G>A p.R295H | Missense Mutation (SNP) | VAF 20/376 reads (5%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1342616722, COSV61149789; called by muse, mutect2
- FGD1 | c.31G>A p.G11R | Missense Mutation (SNP) | VAF 24/435 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.956); catalogued as COSV64308518; called by muse, mutect2
- FGF19 | c.256G>A p.A86T | Missense Mutation (SNP) | VAF 12/266 reads (5%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.803); catalogued as COSV99594322; called by muse, mutect2
- FLT4 | c.2921C>T p.P974L | Missense Mutation (SNP) | VAF 20/536 reads (4%) | SIFT tolerated (0.48); PolyPhen benign (0.009); catalogued as COSV99986823; called by muse, mutect2
- FLT4 | c.2228C>T p.A743V | Missense Mutation (SNP) | VAF 22/390 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.952); catalogued as COSV56098861; called by muse, mutect2
- FMR1 | c.1579C>T p.R527C | Missense Mutation (SNP) | VAF 21/534 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs782089884; called by muse, mutect2
- FOXI2 | c.805G>A p.D269N | Missense Mutation (SNP) | VAF 18/430 reads (4%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.534); catalogued as rs1248195451; called by muse, mutect2
- FREM1 | c.4145A>G p.D1382G | Missense Mutation (SNP) | VAF 15/254 reads (6%) | SIFT tolerated (0.06); PolyPhen benign (0.101); catalogued as rs1423465457; called by muse, mutect2
- FZD2 | c.1264G>A p.V422M | Missense Mutation (SNP) | VAF 18/332 reads (5%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.95); catalogued as rs1339183245, COSV59527929; called by muse, mutect2
- FZD8 | c.1531C>T p.R511C | Missense Mutation (SNP) | VAF 12/332 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV65967972; called by muse, mutect2
- GABRB2 | c.1457C>T p.A486V (on ENST00000274547; = p.A448V on NM_000813.3) | Missense Mutation (SNP) | VAF 12/357 reads (3%) | SIFT tolerated (0.71); PolyPhen possibly damaging (0.491); catalogued as COSV99195585; called by muse, mutect2
- GEMIN7 | c.94G>T p.A32S | Missense Mutation (SNP) | VAF 15/432 reads (3%) | SIFT tolerated (0.24); PolyPhen benign (0.142); catalogued as COSV54320067; called by muse, mutect2
- GEMIN8 | c.500G>A p.R167H | Missense Mutation (SNP) | VAF 19/367 reads (5%) | SIFT tolerated (0.37); PolyPhen benign (0.067); catalogued as rs1487468361, COSV60551149; called by muse, mutect2
- GGT1 | c.691G>A p.G231S | Missense Mutation (SNP) | VAF 36/372 reads (10%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.987); catalogued as rs1023651609; called by muse, mutect2
- GLI2 | c.3013G>A p.G1005S (on ENST00000361492 / NM_001374353.1; = p.G1022S on NM_005270.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 28/482 reads (6%) | SIFT tolerated (0.35); PolyPhen benign (0.011); catalogued as rs1476635342, COSV58049004; called by muse, mutect2
- GLYATL1B | c.748C>T p.R250* | Nonsense Mutation (SNP) | VAF 20/362 reads (6%) | catalogued as rs984706715; called by muse, mutect2
- GMIP | c.2786C>T p.P929L | Missense Mutation (SNP) | VAF 22/466 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.248); catalogued as rs994295052; called by muse, mutect2
- GMIP | c.1490G>A p.R497Q | Missense Mutation (SNP) | VAF 30/434 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as rs138615732; called by muse, mutect2
- GOPC | c.517G>T p.A173S | Missense Mutation (SNP) | VAF 14/342 reads (4%) | SIFT tolerated (0.21); PolyPhen benign (0.028); catalogued as COSV50001714; called by muse, mutect2
- GPR25 | c.1036G>A p.V346M | Missense Mutation (SNP) | VAF 17/333 reads (5%) | SIFT tolerated (0.24); PolyPhen benign (0.028); catalogued as COSV58498212; called by muse, mutect2
- GPR88 | c.646G>A p.V216M | Missense Mutation (SNP) | VAF 22/334 reads (7%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.84); catalogued as rs1337892728; called by muse, mutect2
- GRINA | c.931G>A p.V311M | Missense Mutation (SNP) | VAF 15/421 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as rs782658517; called by muse, mutect2
- HK2 | c.727C>T p.R243C | Missense Mutation (SNP) | VAF 15/278 reads (5%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.97); catalogued as rs1230736932, COSV51878766; called by muse, mutect2
- HK2 | c.1717G>A p.E573K | Missense Mutation (SNP) | VAF 12/186 reads (6%) | SIFT tolerated (0.09); PolyPhen benign (0.031); catalogued as rs1266328422, COSV51877676; called by muse, mutect2
- HOXD11 | c.746C>T p.P249L | Missense Mutation (SNP) | VAF 14/359 reads (4%) | SIFT tolerated (0.28); PolyPhen benign (0.123); catalogued as rs1354655194, COSV50910691; called by muse, mutect2
- IDE | c.2002C>T p.R668* | Nonsense Mutation (SNP) | VAF 8/212 reads (4%) | catalogued as COSV56422927; called by muse, mutect2
- IL3RA | c.320C>T p.A107V | Missense Mutation (SNP) | VAF 19/408 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs200007566; called by muse, mutect2
- INSRR | c.1292C>T p.A431V | Missense Mutation (SNP) | VAF 16/310 reads (5%) | SIFT tolerated (0.05); PolyPhen benign (0.039); catalogued as COSV63875690; called by muse, mutect2
- INTS1 | c.3607G>A p.A1203T | Missense Mutation (SNP) | VAF 24/420 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.77); catalogued as COSV67179789; called by muse, mutect2
- IRS1 | c.449G>A p.S150N | Missense Mutation (SNP) | VAF 16/388 reads (4%) | SIFT tolerated (0.61); PolyPhen benign (0.092); catalogued as rs1395545830; called by muse, mutect2
- ITPKC | c.1876C>T p.H626Y | Missense Mutation (SNP) | VAF 16/267 reads (6%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.969); catalogued as COSV99649100; called by muse, mutect2
- JAKMIP2 | c.446G>A p.R149H | Missense Mutation (SNP) | VAF 19/382 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs1276650784, COSV54605362; called by muse, mutect2
- KCNA10 | c.463G>A p.A155T | Missense Mutation (SNP) | VAF 18/327 reads (6%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.879); catalogued as rs867102815; called by muse, mutect2
- KCNA3 | c.1099C>T p.R367C | Missense Mutation (SNP) | VAF 17/350 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100871236, COSV63901810; called by muse, mutect2
- KCNA3 | c.899C>T p.T300M | Missense Mutation (SNP) | VAF 24/408 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63901626; called by muse, mutect2
- KDM4B | c.2753C>T p.A918V | Missense Mutation (SNP) | VAF 19/290 reads (7%) | SIFT tolerated (0.25); PolyPhen benign (0.04); catalogued as rs1354129376; called by muse, mutect2
- KL | c.1722C>A p.D574E | Missense Mutation (SNP) | VAF 18/334 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV66308252; called by muse, mutect2
- KRT12 | c.905G>A p.R302Q | Missense Mutation (SNP) | VAF 22/442 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1266919613; called by muse, mutect2
- LEP | c.335C>T p.A112V | Missense Mutation (SNP) | VAF 24/364 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs1211502716; called by muse, mutect2
- LRFN3 | c.841C>T p.R281C | Missense Mutation (SNP) | VAF 16/438 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs1330142679; called by muse, mutect2
- LRRC18 | c.176G>A p.R59Q | Missense Mutation (SNP) | VAF 14/330 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as rs942007465, COSV53284272; called by muse, mutect2
- LVRN | c.1217del p.K406Rfs*3 | Frame Shift Del (DEL) | VAF 24/224 reads (11%) | catalogued as rs1561560617; called by mutect2, varscan2
- MAGEB1 | c.310G>T p.V104F | Missense Mutation (SNP) | VAF 22/465 reads (5%) | SIFT tolerated (0.69); PolyPhen benign (0.131); catalogued as COSV66775608; called by muse, mutect2
- MAP3K4 | c.784G>A p.E262K | Missense Mutation (SNP) | VAF 14/365 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV62331972; called by muse, mutect2
- MAPKAP1 | c.1286C>T p.P429L (on ENST00000265960 / NM_001006617.3; = p.P393L on NM_024117.3) | Missense Mutation (SNP) | VAF 18/376 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.906); catalogued as COSV56375426; called by muse, mutect2
- MDN1 | c.12445C>T p.R4149C | Missense Mutation (SNP) | VAF 12/297 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); catalogued as rs1007934495; called by muse, mutect2
- MEGF11 | c.1855G>A p.A619T | Missense Mutation (SNP) | VAF 19/428 reads (4%) | SIFT tolerated (0.25); PolyPhen benign (0.037); catalogued as rs747837275; called by muse, mutect2
- MEIOC | c.2492G>A p.R831Q | Missense Mutation (SNP) | VAF 14/322 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.768); catalogued as rs1392194395; called by muse, mutect2
- MMEL1 | c.2252C>T p.S751L | Missense Mutation (SNP) | VAF 14/346 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as rs994963746; called by muse, mutect2
- MUC21 | c.848G>A p.S283N | Missense Mutation (SNP) | VAF 23/484 reads (5%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.961); catalogued as rs575765296; called by muse, mutect2
- MUC4 | c.988G>A p.V330M | Missense Mutation (SNP) | VAF 30/612 reads (5%) | SIFT tolerated, low confidence (0.58); PolyPhen possibly damaging (0.618); catalogued as rs372557419; called by muse, mutect2
- MUC5B | c.10354G>A p.A3452T | Missense Mutation (SNP) | VAF 28/976 reads (3%) | SIFT tolerated (0.14); PolyPhen benign (0.021); catalogued as COSV71591787; called by muse, mutect2
- MYO9B | c.2971C>T p.R991W | Missense Mutation (SNP) | VAF 24/440 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1052806413; called by muse, mutect2
- MYOM2 | c.1072G>A p.V358M | Missense Mutation (SNP) | VAF 33/520 reads (6%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.72); catalogued as rs201045176; called by muse, mutect2
- MYT1 | c.2831C>T p.P944L | Missense Mutation (SNP) | VAF 28/491 reads (6%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.986); catalogued as rs748668395; called by muse, mutect2
- NFATC1 | c.293C>T p.A98V | Missense Mutation (SNP) | VAF 30/441 reads (7%) | SIFT tolerated (0.16); PolyPhen benign (0.009); catalogued as rs373889524, COSV53702050; called by muse, mutect2
- NKD2 | c.916G>A p.V306I | Missense Mutation (SNP) | VAF 18/529 reads (3%) | SIFT tolerated (0.47); PolyPhen benign (0.001); catalogued as rs961858624; called by muse, mutect2
- NKPD1 | c.2062G>A p.A688T | Missense Mutation (SNP) | VAF 12/265 reads (5%) | SIFT tolerated (0.4); PolyPhen benign (0.127); catalogued as rs1459787744; called by muse, mutect2
- NKX2-4 | c.961G>A p.A321T | Missense Mutation (SNP) | VAF 18/416 reads (4%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as COSV61085493; called by muse, mutect2
- NOCT | c.235G>A p.A79T | Missense Mutation (SNP) | VAF 18/266 reads (7%) | SIFT tolerated (0.2); PolyPhen benign (0.007); catalogued as rs1021607953; called by muse, mutect2
- NOTCH1 | c.6208C>T p.R2070W | Missense Mutation (SNP) | VAF 24/337 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1432074829, COSV53049966; called by muse, mutect2
- NPHS1 | c.154C>T p.R52C | Missense Mutation (SNP) | VAF 15/391 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.616); catalogued as rs1431747804, COSV100800024; called by muse, mutect2
- NRBP2 | c.1184G>A p.R395H | Missense Mutation (SNP) | VAF 31/508 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.775); catalogued as rs781994955; called by muse, mutect2
- NRROS | c.868C>A p.L290M | Missense Mutation (SNP) | VAF 15/434 reads (3%) | SIFT deleterious (0.01); PolyPhen benign (0.294); catalogued as rs947354741, COSV60748092; called by muse, mutect2
- NUP210 | c.1787G>A p.G596E | Missense Mutation (SNP) | VAF 10/247 reads (4%) | SIFT deleterious (0.04); PolyPhen benign (0.335); catalogued as COSV54405186; called by muse, mutect2
- NWD1 | c.1028C>A p.P343Q | Missense Mutation (SNP) | VAF 17/440 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.401); catalogued as COSV100343878; called by muse, mutect2
- OLFM1 | c.823C>T p.R275C (on ENST00000371793 / NM_001282611.2; = p.R257C on NM_014279.5) | Missense Mutation (SNP) | VAF 12/253 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.98); catalogued as rs1294050748; called by muse, mutect2
- OR1R1P | c.604G>A p.E202K | Missense Mutation (SNP) | VAF 20/270 reads (7%) | SIFT tolerated (0.55); PolyPhen probably damaging (0.999); catalogued as COSV59799555; called by muse, mutect2
- OR2I1P | c.256G>A p.G86R | Missense Mutation (SNP) | VAF 16/320 reads (5%) | SIFT deleterious (0.04); PolyPhen benign (0.065); catalogued as rs752730866; called by muse, mutect2
- OR51E2 | c.155G>A p.R52H | Missense Mutation (SNP) | VAF 24/388 reads (6%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as rs1341785184, COSV101211408; called by muse, mutect2
- OR8B4 | c.315C>G p.F105L | Missense Mutation (SNP) | VAF 21/305 reads (7%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.012); catalogued as COSV62069305, COSV62069679; called by muse, mutect2
- OSBP | c.668C>T p.T223M | Missense Mutation (SNP) | VAF 22/343 reads (6%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as rs1289383818; called by muse, mutect2
- OSBPL1A | c.571T>C p.C191R | Missense Mutation (SNP) | VAF 21/357 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60195146; called by muse, mutect2
- OTOL1 | c.599G>A p.C200Y | Missense Mutation (SNP) | VAF 20/360 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); catalogued as rs1440237791; called by muse, mutect2
- PCDH10 | c.2102G>A p.R701H | Missense Mutation (SNP) | VAF 15/458 reads (3%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.964); catalogued as COSV52103436; called by muse, mutect2
- PCDHA10 | c.1852C>T p.R618C | Missense Mutation (SNP) | VAF 13/311 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.954); catalogued as rs1554150821, COSV100255194; called by muse, mutect2
- PCDHA12 | c.719C>T p.P240L | Missense Mutation (SNP) | VAF 14/363 reads (4%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (1); catalogued as rs1313911800; called by muse, mutect2
- PCDHA2 | c.1867C>T p.R623C | Missense Mutation (SNP) | VAF 20/262 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.16); catalogued as rs150299243; called by muse, mutect2
- PCDHA3 | c.1489C>T p.R497W | Missense Mutation (SNP) | VAF 38/615 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.932); catalogued as COSV63545026; called by muse, mutect2
- PCDHGA2 | c.1753G>A p.G585S | Missense Mutation (SNP) | VAF 26/485 reads (5%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.983); catalogued as rs1242546924; called by muse, mutect2
- PCSK9 | c.914C>T p.A305V | Missense Mutation (SNP) | VAF 18/482 reads (4%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as rs1239236028; called by muse, mutect2
- PDYN | c.677A>G p.Y226C | Missense Mutation (SNP) | VAF 14/351 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54102066; called by muse, mutect2
- PDZD4 | c.1823G>A p.R608Q | Missense Mutation (SNP) | VAF 24/543 reads (4%) | SIFT tolerated (0.25); PolyPhen benign (0.015); catalogued as rs782022541; called by muse, mutect2
- PKD1L1 | c.7372C>T p.R2458* | Nonsense Mutation (SNP) | VAF 18/278 reads (6%) | catalogued as rs1232542682; called by muse, mutect2
- PLEC | c.2953G>A p.E985K (on ENST00000322810 / NM_201380.4; = p.E875K on NM_000445.5) | Missense Mutation (SNP) | VAF 22/496 reads (4%) | SIFT deleterious (0.02); PolyPhen benign (0.011); catalogued as rs781977174; ClinVar: uncertain significance; called by muse, mutect2
- PLEC | c.2770C>T p.R924W (on ENST00000322810 / NM_201380.4; = p.R814W on NM_000445.5) | Missense Mutation (SNP) | VAF 16/486 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as rs782306099; called by muse, mutect2
- PLXNB2 | c.212C>T p.P71L | Missense Mutation (SNP) | VAF 16/412 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1233673658, COSV63781813; called by muse, mutect2
- PNLIPRP1 | c.886G>A p.D296N | Missense Mutation (SNP) | VAF 13/260 reads (5%) | SIFT tolerated (0.13); PolyPhen benign (0.013); catalogued as rs959649900, COSV62611937; called by muse, mutect2
- PNMA8B | c.715G>A p.A239T | Missense Mutation (SNP) | VAF 13/421 reads (3%) | SIFT tolerated (0.08); PolyPhen benign (0.329); catalogued as rs1328810813; called by muse, mutect2
- POR | c.1748C>T p.A583V | Missense Mutation (SNP) | VAF 15/406 reads (4%) | SIFT tolerated (0.07); PolyPhen benign (0.059); catalogued as rs1222277700; called by muse, mutect2
- PRAF2 | c.56C>T p.S19L | Missense Mutation (SNP) | VAF 15/444 reads (3%) | SIFT tolerated (0.16); PolyPhen benign (0.125); catalogued as COSV59876843; called by muse, mutect2
- PRDM12 | c.222C>T p.G74= | Splice Region (SNP) | VAF 10/202 reads (5%) | catalogued as rs997823590; called by muse, mutect2
- PREX2 | c.1537G>A p.A513T | Missense Mutation (SNP) | VAF 10/193 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs1323273757; called by muse, mutect2
- PRPF39 | c.692G>A p.R231H | Missense Mutation (SNP) | VAF 11/214 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV104418904, COSV63276880; called by muse, mutect2
- PRPS1L1 | c.694G>A p.A232T | Missense Mutation (SNP) | VAF 12/296 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as rs1336330353, COSV72649781; called by muse, mutect2
- PRR12 | c.122C>T p.A41V (on ENST00000615927; = p.A862V on NM_020719.3) | Missense Mutation (SNP) | VAF 28/396 reads (7%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.003); catalogued as rs1338254496; called by muse, mutect2
- PRR23C | c.257C>T p.S86L | Missense Mutation (SNP) | VAF 15/381 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs904602214; called by muse, mutect2
- PRRC2A | c.3011C>T p.S1004F | Missense Mutation (SNP) | VAF 32/610 reads (5%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.003); catalogued as rs1300392878; called by muse, mutect2
- PXDN | c.2308G>A p.V770M | Missense Mutation (SNP) | VAF 14/362 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.91); catalogued as COSV99412177; called by muse, mutect2
- QRFPR | c.229C>T p.R77C | Missense Mutation (SNP) | VAF 20/422 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100543980; called by muse, mutect2
- RADIL | c.1856C>T p.A619V | Missense Mutation (SNP) | VAF 26/430 reads (6%) | SIFT tolerated (0.24); PolyPhen benign (0.077); catalogued as rs1218336233; called by muse, mutect2
- RAET1E | c.617C>T p.P206L | Missense Mutation (SNP) | VAF 25/282 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.027); catalogued as rs762248395, COSV100593458, COSV61722767; called by muse, mutect2
- RBM10 | c.62G>A p.R21H | Missense Mutation (SNP) | VAF 14/457 reads (3%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.964); catalogued as COSV61312822; called by muse, mutect2
- REEP1 | c.490G>A p.A164T | Missense Mutation (SNP) | VAF 26/472 reads (6%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as rs1351359618, COSV51257608; called by muse, mutect2
- RGS9 | c.1522G>A p.A508T | Missense Mutation (SNP) | VAF 30/506 reads (6%) | SIFT tolerated, low confidence (0.46); PolyPhen benign (0); catalogued as rs1295344167, COSV52225249; called by muse, mutect2
- RIC8A | c.632C>T p.T211M | Missense Mutation (SNP) | VAF 16/375 reads (4%) | SIFT tolerated (0.11); PolyPhen benign (0.007); catalogued as rs1328851397; called by muse, mutect2
- RIMS2 | c.1513G>A p.G505S (on ENST00000666250 / NM_001348490.2; = p.G313S on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 59/373 reads (16%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.995); catalogued as rs200234707, COSV51700356; called by muse, mutect2, varscan2
- SAFB | c.2491C>T p.R831W | Missense Mutation (SNP) | VAF 20/419 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1343413973, COSV52650595; called by muse, mutect2
- SEMA4A | c.826G>A p.E276K | Missense Mutation (SNP) | VAF 8/154 reads (5%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.612); catalogued as COSV61773805; called by muse, mutect2
- SHCBP1 | c.781T>A p.F261I | Missense Mutation (SNP) | VAF 14/298 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV57650444; called by muse, mutect2
- SLC16A11 | c.929G>A p.R310Q (on ENST00000308009; = p.R286Q on NM_153357.3) | Missense Mutation (SNP) | VAF 28/584 reads (5%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.946); catalogued as COSV57274958; called by muse, mutect2
- SLC25A29 | c.667C>T p.R223W (on ENST00000359232 / NM_001039355.3; = p.R157W on NM_152333.4 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 26/379 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.474); catalogued as rs1208323105; called by muse, mutect2
- SLC2A12 | c.500T>C p.L167P | Missense Mutation (SNP) | VAF 26/420 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1202528513; called by muse, mutect2
- SLC39A12 | c.496G>A p.D166N | Missense Mutation (SNP) | VAF 12/300 reads (4%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.948); catalogued as rs782714669; called by muse, mutect2
- SLX4 | c.4739G>T p.R1580M | Missense Mutation (SNP) | VAF 21/249 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99567889, COSV99568126; called by muse, mutect2
- SMARCC1 | c.2354C>A p.P785H | Missense Mutation (SNP) | VAF 16/343 reads (5%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.497); catalogued as rs1258635101; called by muse, mutect2
- SMARCC2 | c.2608G>A p.A870T | Missense Mutation (SNP) | VAF 12/328 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1166403953, COSV57223364; called by muse, mutect2
- SMARCD3 | c.838C>T p.R280C (on ENST00000262188 / NM_001003801.2; = p.R267C on NM_003078.4) | Missense Mutation (SNP) | VAF 24/442 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.584); catalogued as rs1195534343, COSV99222804; called by muse, mutect2
- SNAPC4 | c.2702G>A p.R901Q | Missense Mutation (SNP) | VAF 15/445 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1405212944, COSV53740077; called by muse, mutect2
- SORBS2 | c.1112C>T p.T371M | Missense Mutation (SNP) | VAF 18/362 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV52995768; called by muse, mutect2
- SOX18 | c.466C>T p.P156S | Missense Mutation (SNP) | VAF 22/325 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1349098087; called by muse, mutect2
- SP9 | c.721G>A p.A241T | Missense Mutation (SNP) | VAF 17/440 reads (4%) | SIFT tolerated (0.3); PolyPhen benign (0.014); catalogued as COSV67602008; called by muse, mutect2
- SPATA31A1 | c.3986G>A p.G1329D | Missense Mutation (SNP) | VAF 24/482 reads (5%) | SIFT tolerated (0.08); PolyPhen benign (0.437); catalogued as COSV66533977; called by muse, mutect2
- SRCAP | c.2591G>A p.R864H | Missense Mutation (SNP) | VAF 15/323 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1337092744; called by muse, mutect2
- SRD5A2 | c.43G>A p.A15T | Missense Mutation (SNP) | VAF 17/339 reads (5%) | SIFT tolerated (0.39); PolyPhen benign (0.055); catalogued as COSV51873525; called by muse, mutect2
- SSBP4 | c.378del p.G127Afs*13 | Frame Shift Del (DEL) | VAF 10/99 reads (10%) | catalogued as rs760883618; called by mutect2, pindel
- STAT5B | c.674A>G p.Y225C | Missense Mutation (SNP) | VAF 12/216 reads (6%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.921); catalogued as COSV99510960; called by muse, mutect2
- SYNE1 | c.2548C>A p.L850I (on ENST00000367255 / NM_182961.4; = p.L857I on NM_033071.3) | Missense Mutation (SNP) | VAF 18/282 reads (6%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as COSV55059596; called by muse, mutect2
- SYT2 | c.1126G>A p.V376M | Missense Mutation (SNP) | VAF 16/348 reads (5%) | SIFT tolerated (0.09); PolyPhen benign (0.283); catalogued as rs1310108702; called by muse, mutect2
- TAF4 | c.1240C>T p.R414W | Missense Mutation (SNP) | VAF 22/472 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.898); catalogued as rs1404427235; called by muse, mutect2
- TBC1D9B | c.1540C>T p.R514W | Missense Mutation (SNP) | VAF 15/340 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1419302814; called by muse, mutect2
- TBXA2R | c.176C>T p.T59M | Missense Mutation (SNP) | VAF 29/422 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.264); catalogued as rs1306012893, COSV64343321; called by muse, mutect2
- TIAM1 | c.25G>A p.V9I | Missense Mutation (SNP) | VAF 17/303 reads (6%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.294); catalogued as rs1290218030; called by muse, mutect2
- TMC7 | c.782C>T p.T261I | Missense Mutation (SNP) | VAF 19/328 reads (6%) | SIFT tolerated (0.11); PolyPhen benign (0.127); catalogued as COSV58581617; called by muse, mutect2
- TMCC3 | c.773C>T p.S258L | Missense Mutation (SNP) | VAF 17/261 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.28); catalogued as COSV99705272; called by muse, mutect2
- TMEM151A | c.647C>T p.T216M | Missense Mutation (SNP) | VAF 22/494 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV59173693; called by muse, mutect2
- TMEM184A | c.896C>T p.T299M | Missense Mutation (SNP) | VAF 18/368 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs985285082, COSV99033946; called by muse, mutect2
- TMEM200C | c.1208G>A p.R403K | Missense Mutation (SNP) | VAF 20/416 reads (5%) | SIFT tolerated (0.3); PolyPhen benign (0.003); catalogued as rs1293246960; called by muse, mutect2
- TNIK | c.391G>A p.A131T | Missense Mutation (SNP) | VAF 16/324 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.426); catalogued as COSV99454002; called by muse, mutect2
- TNNI3 | c.465G>A p.M155I | Missense Mutation (SNP) | VAF 14/380 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.007); catalogued as CM122339; called by muse, mutect2
- TPCN2 | c.1742C>T p.A581V | Missense Mutation (SNP) | VAF 14/334 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.907); catalogued as rs1263924635; called by muse, mutect2
- UBE2L5 | c.44G>A p.R15H | Missense Mutation (SNP) | VAF 20/382 reads (5%) | SIFT tolerated (0.16); PolyPhen benign (0.011); catalogued as rs1358741889; called by muse, mutect2
- UBR2 | c.3121C>T p.R1041C | Missense Mutation (SNP) | VAF 16/349 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs1363359926; called by muse, mutect2
- UHRF2 | c.1391A>G p.Q464R | Missense Mutation (SNP) | VAF 9/160 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1362120274; called by muse, mutect2
- USP35 | c.83C>T p.A28V | Missense Mutation (SNP) | VAF 18/376 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.059); catalogued as rs1207180370, COSV71572762, COSV71572818; called by muse, mutect2
- VAMP2 | c.22G>C p.A8P | Missense Mutation (SNP) | VAF 15/452 reads (3%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0); catalogued as rs1266146036, COSV100336106; called by muse, mutect2
- VTN | c.1193G>A p.R398H | Missense Mutation (SNP) | VAF 16/386 reads (4%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.869); catalogued as rs201964332, COSV99412239; called by muse, mutect2
- WDR13 | c.437G>A p.R146Q | Missense Mutation (SNP) | VAF 24/436 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.856); catalogued as rs1556993825, COSV99489132; called by muse, mutect2
- WDR62 | c.704C>T p.T235M | Missense Mutation (SNP) | VAF 10/288 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs948741011, COSV54337121; called by muse, mutect2
- XKR6 | c.274del p.D92Tfs*73 | Frame Shift Del (DEL) | VAF 12/120 reads (10%) | catalogued as rs1403895317; called by mutect2, pindel
- ZDBF2 | c.5449C>A p.L1817I | Missense Mutation (SNP) | VAF 15/352 reads (4%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.976); catalogued as COSV65625220; called by muse, mutect2
- ZEB2 | c.506G>A p.R169H | Missense Mutation (SNP) | VAF 26/471 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.862); catalogued as rs1414304969, COSV100356387; called by muse, mutect2
- ZFAT | c.1369G>A p.V457M | Missense Mutation (SNP) | VAF 30/442 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.862); catalogued as rs374100557; called by muse, mutect2
- ZFHX2 | c.4909C>A p.R1637S | Missense Mutation (SNP) | VAF 19/407 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV70220155; called by muse, mutect2
- ZFP2 | c.1114C>T p.H372Y | Missense Mutation (SNP) | VAF 14/287 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs890608919; called by muse, mutect2
- ZIC1 | c.412G>A p.A138T | Missense Mutation (SNP) | VAF 25/419 reads (6%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as COSV51555616; called by muse, mutect2
- ZNF284 | c.397G>A p.V133I | Missense Mutation (SNP) | VAF 14/328 reads (4%) | SIFT tolerated (0.35); PolyPhen benign (0.005); catalogued as COSV69691573; called by muse, mutect2
- ZNF382 | c.1386A>C p.K462N | Missense Mutation (SNP) | VAF 15/322 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.757); catalogued as COSV53088070; called by muse, mutect2
- ZNF575 | c.451G>A p.D151N | Missense Mutation (SNP) | VAF 24/386 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.579); catalogued as rs1365189071; called by muse, mutect2
- AASDH | c.1472C>T p.A491V | Missense Mutation (SNP) | VAF 12/285 reads (4%) | SIFT tolerated (0.27); PolyPhen benign (0.019); called by muse, mutect2
- ABCA1 | c.4724A>T p.N1575I | Missense Mutation (SNP) | VAF 14/244 reads (6%) | SIFT tolerated (0.08); PolyPhen benign (0.109); called by muse, mutect2
- ABCA6 | c.2446G>A p.A816T | Missense Mutation (SNP) | VAF 14/336 reads (4%) | SIFT tolerated (0.62); PolyPhen benign (0.001); called by muse, mutect2
- ABCB7 | c.1354A>G p.T452A (on ENST00000373394 / NM_001271696.3; = p.T453A on NM_004299.6) | Missense Mutation (SNP) | VAF 10/177 reads (6%) | SIFT tolerated (0.55); PolyPhen benign (0); called by muse, mutect2
- ACAD8 | c.506C>T p.A169V | Missense Mutation (SNP) | VAF 16/351 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ADAM22 | c.1430G>A p.C477Y | Missense Mutation (SNP) | VAF 12/244 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ADAMTS15 | c.1283G>C p.S428T | Missense Mutation (SNP) | VAF 14/394 reads (4%) | SIFT tolerated (0.69); PolyPhen benign (0.013); called by muse, mutect2
- ADAMTS4 | c.2243C>T p.P748L | Missense Mutation (SNP) | VAF 14/352 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.01); called by muse, mutect2
- ADCK2 | c.1313T>C p.V438A | Missense Mutation (SNP) | VAF 14/211 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.26); called by muse, mutect2
- ADCY8 | c.196G>A p.G66S | Missense Mutation (SNP) | VAF 19/446 reads (4%) | SIFT tolerated (0.73); PolyPhen benign (0); called by muse, mutect2
- ADGRF1 | c.976T>C p.F326L | Missense Mutation (SNP) | VAF 14/334 reads (4%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- ADRA2C | c.769T>C p.S257P | Missense Mutation (SNP) | VAF 20/364 reads (5%) | SIFT tolerated (0.14); PolyPhen benign (0.018); called by muse, mutect2
- ADSL | c.1085T>G p.L362W | Missense Mutation (SNP) | VAF 10/246 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- AKNAD1 | c.2053A>T p.T685S | Missense Mutation (SNP) | VAF 14/194 reads (7%) | SIFT tolerated (0.43); PolyPhen benign (0); called by muse, mutect2
- ALOX12B | c.1373T>C p.L458P | Missense Mutation (SNP) | VAF 12/306 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.179); called by muse, mutect2
- APOB | c.12616G>T p.G4206W | Missense Mutation (SNP) | VAF 20/309 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ARSD | c.1198G>A p.G400R | Missense Mutation (SNP) | VAF 32/581 reads (6%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.611); called by muse, mutect2
- ASAH1 | c.181G>T p.G61C | Missense Mutation (SNP) | VAF 14/205 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); called by muse, mutect2
- ASXL1 | c.4476G>A p.M1492I | Missense Mutation (SNP) | VAF 10/323 reads (3%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); called by muse, mutect2
- ATP11C | c.3106T>C p.Y1036H | Missense Mutation (SNP) | VAF 12/270 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); called by muse, mutect2
- ATP13A2 | c.1438T>C p.C480R | Missense Mutation (SNP) | VAF 22/410 reads (5%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.664); called by muse, mutect2
- ATP2C1 | c.1924A>G p.T642A | Missense Mutation (SNP) | VAF 14/280 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ATRNL1 | c.2056T>C p.C686R | Missense Mutation (SNP) | VAF 12/316 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.564); called by muse, mutect2
- BMP8A | c.137G>A p.R46H | Missense Mutation (SNP) | VAF 16/350 reads (5%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.989); called by muse, mutect2
- BSN | c.8237G>A p.G2746D | Missense Mutation (SNP) | VAF 22/420 reads (5%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.573); called by muse, mutect2
- BTBD8 | c.4958A>C p.D1653A (on ENST00000636805 / NM_001376131.1; = p.D1140A on NM_015237.4) | Missense Mutation (SNP) | VAF 21/326 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- BTK | c.151A>C p.S51R | Missense Mutation (SNP) | VAF 14/245 reads (6%) | SIFT tolerated (0.41); PolyPhen benign (0.286); called by muse, mutect2
- C19orf18 | c.583C>T p.Q195* | Nonsense Mutation (SNP) | VAF 14/228 reads (6%) | called by muse, mutect2
- C5 | c.1070T>A p.V357D | Missense Mutation (SNP) | VAF 18/279 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.768); called by muse, mutect2
- CACNA1H | c.3623C>T p.A1208V | Missense Mutation (SNP) | VAF 22/531 reads (4%) | SIFT tolerated (0.25); PolyPhen benign (0.026); called by muse, mutect2
- CATSPER4 | c.632T>C p.V211A | Missense Mutation (SNP) | VAF 14/313 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.266); called by muse, mutect2
- CD101 | c.2635A>G p.R879G | Missense Mutation (SNP) | VAF 18/445 reads (4%) | SIFT tolerated (0.24); PolyPhen benign (0.001); called by muse, mutect2
- CD276 | c.751G>A p.V251I | Missense Mutation (SNP) | VAF 18/266 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); called by muse, mutect2
- CD80 | c.605G>A p.S202N | Missense Mutation (SNP) | VAF 20/390 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2
- CD96 | c.781A>G p.T261A (on ENST00000283285 / NM_198196.3; = p.T245A on NM_005816.5) | Missense Mutation (SNP) | VAF 11/264 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.433); called by muse, mutect2
- CDYL | c.994G>A p.V332M (on ENST00000328908 / NM_001368125.1; = p.V278M on NM_004824.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 30/472 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); called by muse, mutect2
- CENPVL3 | c.191C>T p.A64V | Missense Mutation (SNP) | VAF 23/492 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.031); called by muse, mutect2
- CEP170B | c.2125A>G p.R709G (on ENST00000453495; = p.R638G on NM_015005.3) | Missense Mutation (SNP) | VAF 28/470 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2
- CEP192 | c.530T>G p.L177R | Missense Mutation (SNP) | VAF 13/174 reads (7%) | SIFT tolerated (0.28); PolyPhen benign (0.366); called by muse, mutect2
- CHIT1 | c.394T>G p.F132V | Missense Mutation (SNP) | VAF 18/414 reads (4%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); called by muse, mutect2
- CHRNA5 | c.1154G>A p.G385E | Missense Mutation (SNP) | VAF 12/299 reads (4%) | SIFT tolerated (0.24); PolyPhen benign (0.124); called by muse, mutect2
- CLCN3 | c.1594G>A p.A532T | Missense Mutation (SNP) | VAF 19/319 reads (6%) | SIFT tolerated (0.07); PolyPhen benign (0.363); called by muse, mutect2
- CLIP2 | c.2774G>T p.G925V | Missense Mutation (SNP) | VAF 14/360 reads (4%) | SIFT tolerated (0.55); PolyPhen possibly damaging (0.855); called by muse, mutect2
- CNGA4 | c.73C>T p.P25S | Missense Mutation (SNP) | VAF 12/232 reads (5%) | SIFT tolerated (0.4); PolyPhen benign (0.053); called by muse, mutect2
- CNKSR2 | c.1882G>T p.A628S | Missense Mutation (SNP) | VAF 18/270 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- COL4A3 | c.2951A>G p.K984R | Missense Mutation (SNP) | VAF 16/324 reads (5%) | SIFT tolerated (0.29); PolyPhen benign (0.023); called by muse, mutect2
- COLEC10 | c.183G>T p.E61D | Missense Mutation (SNP) | VAF 16/346 reads (5%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.551); called by muse, mutect2
- COPG1 | c.1130T>C p.V377A | Missense Mutation (SNP) | VAF 11/218 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.973); called by muse, mutect2
- CP | c.272G>A p.G91E | Missense Mutation (SNP) | VAF 14/196 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- CRYBG1 | c.3992A>G p.E1331G | Missense Mutation (SNP) | VAF 22/332 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2
- CSPG4 | c.4779C>A p.C1593* | Nonsense Mutation (SNP) | VAF 20/240 reads (8%) | called by muse, mutect2
- CTBP1 | c.1222T>C p.S408P | Missense Mutation (SNP) | VAF 14/374 reads (4%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0); called by muse, mutect2
- CUX1 | c.2977C>T p.Q993* | Nonsense Mutation (SNP) | VAF 22/402 reads (5%) | called by muse, mutect2
- CYP4X1 | c.1265A>C p.N422T | Missense Mutation (SNP) | VAF 17/250 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.703); called by muse, mutect2
- CYTH3 | c.637C>A p.P213T | Missense Mutation (SNP) | VAF 17/348 reads (5%) | SIFT tolerated (0.07); PolyPhen benign (0.384); called by muse, mutect2
- DAGLB | c.833G>A p.C278Y | Missense Mutation (SNP) | VAF 13/294 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.595); called by muse, mutect2
- DGKA | c.1919A>G p.D640G | Missense Mutation (SNP) | VAF 16/256 reads (6%) | SIFT tolerated (0.15); PolyPhen benign (0.012); called by muse, mutect2
- DIAPH1 | c.2249C>T p.P750L | Missense Mutation (SNP) | VAF 18/327 reads (6%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.999); called by muse, mutect2
- DIP2A | c.3166A>G p.I1056V | Missense Mutation (SNP) | VAF 12/273 reads (4%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.657); called by muse, mutect2
- DISP3 | c.2183G>A p.S728N | Missense Mutation (SNP) | VAF 14/244 reads (6%) | SIFT tolerated (0.33); PolyPhen benign (0.001); called by muse, mutect2
- DISP3 | c.3875C>T p.A1292V | Missense Mutation (SNP) | VAF 17/351 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- DLGAP1 | c.62A>T p.D21V | Missense Mutation (SNP) | VAF 16/410 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.824); called by muse, mutect2
- DNAH17 | c.3929A>G p.D1310G | Missense Mutation (SNP) | VAF 24/295 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2
- DNAH2 | c.1735G>A p.E579K | Missense Mutation (SNP) | VAF 16/292 reads (5%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.842); called by muse, mutect2
- DNAH5 | c.12102G>T p.K4034N | Missense Mutation (SNP) | VAF 14/287 reads (5%) | SIFT tolerated (0.21); PolyPhen benign (0.013); called by muse, mutect2
- DNAL4 | c.160G>A p.A54T | Missense Mutation (SNP) | VAF 12/228 reads (5%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.924); called by muse, mutect2
- DOCK3 | c.4166G>T p.R1389M | Missense Mutation (SNP) | VAF 18/399 reads (5%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.872); called by muse, mutect2
- DTX1 | c.488C>T p.T163M | Missense Mutation (SNP) | VAF 16/396 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.031); called by muse, mutect2
- DTX3 | c.26C>T p.A9V | Missense Mutation (SNP) | VAF 12/222 reads (5%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.487); called by muse, mutect2
- DUSP5 | c.248T>G p.V83G | Missense Mutation (SNP) | VAF 16/313 reads (5%) | SIFT tolerated (0.12); PolyPhen benign (0.142); called by muse, mutect2
- DYTN | c.944T>C p.V315A | Missense Mutation (SNP) | VAF 22/273 reads (8%) | SIFT tolerated (0.17); PolyPhen benign (0.024); called by muse, mutect2
- EIF3A | c.1657G>A p.A553T | Missense Mutation (SNP) | VAF 15/268 reads (6%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.989); called by muse, mutect2
- ELFN1 | c.1676C>A p.A559D | Missense Mutation (SNP) | VAF 21/404 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- EMB | c.77C>T p.A26V | Missense Mutation (SNP) | VAF 16/318 reads (5%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0.001); called by muse, mutect2
- ENO3 | c.163G>T p.G55C | Missense Mutation (SNP) | VAF 14/308 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.501); called by muse, mutect2
- ENOX2 | c.697G>C p.E233Q (on ENST00000338144 / NM_001382520.1; = p.E204Q on NM_006375.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 19/460 reads (4%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.926); called by muse, mutect2
- EP300 | c.5534A>G p.Q1845R | Missense Mutation (SNP) | VAF 17/396 reads (4%) | SIFT tolerated (0.21); PolyPhen benign (0.157); called by muse, mutect2
- EPHB1 | c.1484G>A p.G495E | Missense Mutation (SNP) | VAF 21/408 reads (5%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.501); called by muse, mutect2
- EPOR | c.1000C>T p.L334F | Missense Mutation (SNP) | VAF 22/437 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- EPS15L1 | c.1943C>T p.A648V | Missense Mutation (SNP) | VAF 16/343 reads (5%) | SIFT tolerated (0.07); PolyPhen benign (0.022); called by muse, mutect2
- FAM120C | c.2798C>T p.S933F | Missense Mutation (SNP) | VAF 14/409 reads (3%) | SIFT tolerated (0.69); PolyPhen possibly damaging (0.488); called by muse, mutect2
- FAM71D | c.655A>G p.M219V | Missense Mutation (SNP) | VAF 20/352 reads (6%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); called by muse, mutect2
- FARSB | c.1102G>A p.A368T | Missense Mutation (SNP) | VAF 16/281 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.749); called by muse, mutect2
- FASTKD1 | c.2237G>A p.S746N | Missense Mutation (SNP) | VAF 18/318 reads (6%) | SIFT tolerated (0.15); PolyPhen benign (0.006); called by muse, mutect2
- FAT2 | c.8200A>C p.S2734R | Missense Mutation (SNP) | VAF 24/376 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); called by muse, mutect2
- FBN1 | c.3362C>T p.P1121L | Missense Mutation (SNP) | VAF 9/210 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- FDX2 | c.328G>T p.A110S | Missense Mutation (SNP) | VAF 16/311 reads (5%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.787); called by muse, mutect2
- FGD1 | c.2039G>A p.W680* | Nonsense Mutation (SNP) | VAF 18/349 reads (5%) | called by muse, mutect2
- FGD5 | c.1030G>T p.G344* | Nonsense Mutation (SNP) | VAF 23/384 reads (6%) | called by muse, mutect2
- FLG | c.3476A>G p.Q1159R | Missense Mutation (SNP) | VAF 23/479 reads (5%) | SIFT tolerated (0.78); PolyPhen benign (0); called by muse, mutect2
- FLNA | c.2573C>A p.P858H | Missense Mutation (SNP) | VAF 14/405 reads (3%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2
- FRMD5 | c.641A>G p.D214G | Missense Mutation (SNP) | VAF 14/216 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- FZD5 | c.794G>A p.R265H | Missense Mutation (SNP) | VAF 24/379 reads (6%) | SIFT tolerated (0.1); PolyPhen benign (0.085); called by muse, mutect2
- GAK | c.3425G>A p.C1142Y | Missense Mutation (SNP) | VAF 18/422 reads (4%) | SIFT tolerated (0.07); PolyPhen benign (0.105); called by muse, mutect2
- GAREM1 | c.1151A>G p.H384R | Missense Mutation (SNP) | VAF 25/386 reads (6%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.991); called by muse, mutect2
- GATA5 | c.253G>A p.A85T | Missense Mutation (SNP) | VAF 24/487 reads (5%) | SIFT tolerated (0.15); PolyPhen benign (0.009); called by muse, mutect2
- GCC1 | c.293C>T p.A98V | Missense Mutation (SNP) | VAF 16/384 reads (4%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); called by muse, mutect2
- GLI2 | c.722C>T p.A241V | Missense Mutation (SNP) | VAF 16/410 reads (4%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.776); called by muse, mutect2
- GPR108 | c.392A>G p.Y131C | Missense Mutation (SNP) | VAF 12/193 reads (6%) | SIFT tolerated (0.16); PolyPhen benign (0.428); called by muse, mutect2
- GPR20 | c.32C>T p.A11V | Missense Mutation (SNP) | VAF 12/394 reads (3%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0); called by muse, mutect2
- GPR78 | c.869A>T p.D290V | Missense Mutation (SNP) | VAF 17/371 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- GTF3C4 | c.1366G>T p.D456Y | Missense Mutation (SNP) | VAF 14/293 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.808); called by muse, mutect2
- HECTD4 | c.6410G>A p.G2137D | Missense Mutation (SNP) | VAF 25/391 reads (6%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.691); called by muse, mutect2
- HIC1 | c.832G>A p.A278T (on ENST00000322941 / NM_001098202.1; = p.A259T on NM_006497.4) | Missense Mutation (SNP) | VAF 17/447 reads (4%) | SIFT deleterious (0.04); PolyPhen benign (0); called by muse, mutect2
- HID1 | c.1676G>A p.S559N | Missense Mutation (SNP) | VAF 16/328 reads (5%) | SIFT tolerated (0.81); PolyPhen benign (0); called by muse, mutect2
- HIRA | c.2242G>A p.V748M | Missense Mutation (SNP) | VAF 11/183 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.64); called by muse, mutect2
- HLA-DRA | c.706A>G p.I236V | Missense Mutation (SNP) | VAF 20/545 reads (4%) | SIFT tolerated (0.8); PolyPhen benign (0.003); called by muse, mutect2
- HOXD1 | c.94G>A p.A32T | Missense Mutation (SNP) | VAF 26/402 reads (6%) | SIFT tolerated (0.13); PolyPhen benign (0.001); called by muse, mutect2
- HS6ST3 | c.277G>A p.E93K | Missense Mutation (SNP) | VAF 18/252 reads (7%) | SIFT tolerated, low confidence (0.92); PolyPhen benign (0.007); called by muse, mutect2
- HTR7 | c.289G>A p.A97T | Missense Mutation (SNP) | VAF 23/441 reads (5%) | SIFT tolerated (0.07); PolyPhen benign (0.248); called by muse, mutect2
- HYOU1 | c.2297A>C p.E766A | Missense Mutation (SNP) | VAF 15/330 reads (5%) | SIFT tolerated (0.06); PolyPhen benign (0.097); called by muse, mutect2
- ICAM4 | c.668A>G p.N223S | Missense Mutation (SNP) | VAF 20/344 reads (6%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- INPP1 | c.1054G>A p.V352M | Missense Mutation (SNP) | VAF 14/375 reads (4%) | SIFT tolerated (0.06); PolyPhen benign (0.163); called by muse, mutect2
- INTS6 | c.1486G>A p.A496T | Missense Mutation (SNP) | VAF 16/319 reads (5%) | SIFT tolerated (0.39); PolyPhen benign (0.045); called by muse, mutect2
- IRAK2 | c.1373A>G p.Y458C | Missense Mutation (SNP) | VAF 22/396 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); called by muse, mutect2
- IRX2 | c.74C>T p.A25V | Missense Mutation (SNP) | VAF 15/323 reads (5%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.46); called by muse, mutect2
- IRX4 | c.214G>A p.V72I | Missense Mutation (SNP) | VAF 18/448 reads (4%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.969); called by muse, mutect2
- ITM2A | c.602C>T p.A201V | Missense Mutation (SNP) | VAF 14/351 reads (4%) | SIFT tolerated (1); PolyPhen benign (0.017); called by muse, mutect2
- KANK2 | c.628C>A p.P210T | Missense Mutation (SNP) | VAF 18/395 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- KANSL3 | c.386+1G>A p.X129_splice | Splice Site (SNP) | VAF 10/227 reads (4%) | called by muse, mutect2
- KCNH5 | c.470C>A p.T157K | Missense Mutation (SNP) | VAF 13/249 reads (5%) | SIFT deleterious (0.04); PolyPhen benign (0.08); called by muse, mutect2
- KCNIP3 | c.41G>A p.S14N | Missense Mutation (SNP) | VAF 16/263 reads (6%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0); called by muse, mutect2
- KDM4A | c.366G>A p.W122* | Nonsense Mutation (SNP) | VAF 13/298 reads (4%) | called by muse, mutect2
- KDM6B | c.1820C>A p.P607H | Missense Mutation (SNP) | VAF 24/538 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.022); called by muse, mutect2
- KDM6B | c.3701T>G p.L1234R | Missense Mutation (SNP) | VAF 16/280 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2
- KIAA1549L | c.2879C>T p.A960V (on ENST00000321505; = p.A1257V on NM_012194.3) | Missense Mutation (SNP) | VAF 21/345 reads (6%) | SIFT tolerated (0.41); PolyPhen benign (0.172); called by muse, mutect2
- KIF25 | c.655G>T p.A219S | Missense Mutation (SNP) | VAF 16/302 reads (5%) | SIFT tolerated (0.79); PolyPhen benign (0.033); called by muse, mutect2
- KIF3A | c.287T>C p.I96T | Missense Mutation (SNP) | VAF 10/203 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2
- KIF7 | c.880C>T p.R294C | Missense Mutation (SNP) | VAF 22/360 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- KLF17 | c.611T>C p.V204A | Missense Mutation (SNP) | VAF 17/429 reads (4%) | SIFT tolerated (0.12); PolyPhen benign (0.006); called by muse, mutect2
- KLF2 | c.775C>T p.R259C | Missense Mutation (SNP) | VAF 18/384 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2
- KLF2 | c.962G>A p.R321H | Missense Mutation (SNP) | VAF 19/395 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- KLHL34 | c.607T>C p.W203R | Missense Mutation (SNP) | VAF 24/452 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- KLRG2 | c.362C>A p.P121H | Missense Mutation (SNP) | VAF 26/448 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- KNDC1 | c.1481G>T p.G494V | Missense Mutation (SNP) | VAF 12/329 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- KRTAP10-4 | c.833C>A p.P278H | Missense Mutation (SNP) | VAF 21/431 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.896); called by muse, mutect2
- LHX1 | c.1045C>T p.H349Y | Missense Mutation (SNP) | VAF 21/502 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.821); called by muse, mutect2
- LMF1 | c.589C>T p.P197S | Missense Mutation (SNP) | VAF 20/412 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); called by muse, mutect2
- LOXL1 | c.79C>A p.Q27K | Missense Mutation (SNP) | VAF 18/377 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.05); called by muse, mutect2
- LPP | c.1468G>A p.A490T | Missense Mutation (SNP) | VAF 16/395 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- LRRC1 | c.1313T>G p.L438W | Missense Mutation (SNP) | VAF 16/288 reads (6%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.936); called by muse, mutect2
- LRRC9 | c.3991-1G>A p.X1331_splice | Splice Site (SNP) | VAF 10/158 reads (6%) | called by muse, mutect2
- LRRK1 | c.352C>T p.P118S | Missense Mutation (SNP) | VAF 16/394 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2
- LRRTM3 | c.349A>G p.S117G | Missense Mutation (SNP) | VAF 17/304 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- MAGEL2 | c.2915G>A p.G972D | Missense Mutation (SNP) | VAF 18/418 reads (4%) | SIFT tolerated, low confidence (0.09); PolyPhen possibly damaging (0.804); called by muse, mutect2
- MAP1B | c.6595G>A p.D2199N | Missense Mutation (SNP) | VAF 18/410 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2
- MAP7 | c.1586A>C p.E529A | Missense Mutation (SNP) | VAF 26/414 reads (6%) | SIFT tolerated (0.08); PolyPhen benign (0.306); called by muse, mutect2
- MAPK8IP1 | c.233C>T p.A78V | Missense Mutation (SNP) | VAF 14/288 reads (5%) | SIFT tolerated (0.58); PolyPhen benign (0); called by muse, mutect2
- MARVELD3 | c.891G>A p.W297* | Nonsense Mutation (SNP) | VAF 22/348 reads (6%) | called by muse, mutect2
- MAS1 | c.301C>T p.H101Y | Missense Mutation (SNP) | VAF 20/291 reads (7%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2
- MC2R | c.49A>C p.N17H | Missense Mutation (SNP) | VAF 18/285 reads (6%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.819); called by muse, mutect2
- MCHR2 | c.724C>T p.P242S | Missense Mutation (SNP) | VAF 18/246 reads (7%) | SIFT tolerated (0.27); PolyPhen benign (0.089); called by muse, mutect2
- MCM3AP | c.3794C>T p.A1265V | Missense Mutation (SNP) | VAF 17/344 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- MED12 | c.1408C>T p.R470C | Missense Mutation (SNP) | VAF 20/336 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); called by muse, mutect2
- MFRP | c.61A>G p.S21G (on ENST00000449574; = p.S403G on NM_031433.4) | Missense Mutation (SNP) | VAF 15/325 reads (5%) | SIFT tolerated (0.24); PolyPhen benign (0.003); called by muse, mutect2
- MKI67 | c.2611A>G p.T871A | Missense Mutation (SNP) | VAF 30/374 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0); called by muse, mutect2
- MLLT6 | c.797C>A p.P266H | Missense Mutation (SNP) | VAF 24/458 reads (5%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.548); called by muse, mutect2
- MME | c.1880G>A p.G627E | Missense Mutation (SNP) | VAF 14/320 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- MMP11 | c.940G>A p.G314S | Missense Mutation (SNP) | VAF 22/446 reads (5%) | SIFT tolerated (0.62); PolyPhen benign (0.159); called by muse, mutect2
- MMRN2 | c.1817A>G p.H606R | Missense Mutation (SNP) | VAF 16/428 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- MROH1 | c.3215C>A p.A1072E | Missense Mutation (SNP) | VAF 21/398 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- MROH2B | c.3077C>T p.A1026V | Missense Mutation (SNP) | VAF 14/313 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2
- MUC15 | c.230T>C p.L77P | Missense Mutation (SNP) | VAF 31/345 reads (9%) | SIFT tolerated (0.2); PolyPhen benign (0); called by muse, mutect2
- MYO5B | c.511G>A p.V171I | Missense Mutation (SNP) | VAF 14/279 reads (5%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.531); called by muse, mutect2
- NADK | c.231G>T p.K77N | Missense Mutation (SNP) | VAF 20/316 reads (6%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.969); called by muse, mutect2
- NCOR2 | c.4415A>T p.D1472V | Missense Mutation (SNP) | VAF 20/352 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- NECAP1 | c.278T>C p.V93A | Missense Mutation (SNP) | VAF 10/260 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- NEURL1B | c.1558C>T p.H520Y | Missense Mutation (SNP) | VAF 18/362 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- NLN | c.1582C>T p.P528S | Missense Mutation (SNP) | VAF 19/354 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2
- NME1 | c.185C>T p.A62V | Missense Mutation (SNP) | VAF 24/377 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.039); called by muse, mutect2
- NNT | c.1160T>C p.L387P | Missense Mutation (SNP) | VAF 18/335 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- NPC1 | c.3347T>C p.L1116P | Missense Mutation (SNP) | VAF 22/388 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); called by muse, mutect2
- NPY5R | c.606G>A p.W202* | Nonsense Mutation (SNP) | VAF 18/310 reads (6%) | called by muse, mutect2
- NUDT11 | c.275G>A p.R92K | Missense Mutation (SNP) | VAF 24/526 reads (5%) | SIFT tolerated (0.07); PolyPhen benign (0.425); called by muse, mutect2
- OBSL1 | c.5530G>A p.E1844K | Missense Mutation (SNP) | VAF 19/468 reads (4%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.835); called by muse, mutect2
- OPLAH | c.3043G>T p.G1015C | Missense Mutation (SNP) | VAF 14/326 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- OPLAH | c.2321C>T p.A774V | Missense Mutation (SNP) | VAF 22/482 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- OPLAH | c.941A>G p.D314G | Missense Mutation (SNP) | VAF 13/284 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- OR14J1 | c.837A>G p.I279M | Missense Mutation (SNP) | VAF 16/256 reads (6%) | SIFT tolerated (0.08); PolyPhen benign (0.111); called by muse, mutect2
- OR2AG1 | c.455C>T p.A152V | Missense Mutation (SNP) | VAF 13/279 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); called by muse, mutect2
- OTOP2 | c.889C>A p.L297M | Missense Mutation (SNP) | VAF 21/394 reads (5%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.964); called by muse, mutect2
- PAPPA | c.220G>A p.V74I | Missense Mutation (SNP) | VAF 10/157 reads (6%) | SIFT tolerated, low confidence (0.62); PolyPhen benign (0.001); called by muse, mutect2
- PBXIP1 | c.2029G>A p.D677N | Missense Mutation (SNP) | VAF 12/262 reads (5%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.781); called by muse, mutect2
- PCDH9 | c.941T>C p.V314A | Missense Mutation (SNP) | VAF 20/404 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.939); called by muse, mutect2
- PCDHA10 | c.1501C>T p.R501C | Missense Mutation (SNP) | VAF 26/464 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.967); called by muse, mutect2
- PCDHA13 | c.577T>A p.S193T | Missense Mutation (SNP) | VAF 10/226 reads (4%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.125); called by muse, mutect2
- PDZRN3 | c.269G>A p.G90D | Missense Mutation (SNP) | VAF 26/358 reads (7%) | SIFT tolerated (0.54); PolyPhen benign (0); called by muse, mutect2
- PEG3 | c.2890C>A p.P964T | Missense Mutation (SNP) | VAF 16/367 reads (4%) | SIFT tolerated (0.19); PolyPhen benign (0.041); called by muse, mutect2
- PELI3 | c.1036C>A p.R346S | Missense Mutation (SNP) | VAF 28/420 reads (7%) | SIFT tolerated (0.32); PolyPhen benign (0.391); called by muse, mutect2
- PI4KB | c.1595C>T p.A532V (on ENST00000368873 / NM_001369623.1; = p.A544V on NM_002651.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 14/320 reads (4%) | SIFT tolerated (0.15); PolyPhen benign (0.074); called by muse, mutect2
- PIGN | c.122C>A p.P41H | Missense Mutation (SNP) | VAF 17/326 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); called by muse, mutect2
- PKD1L3 | c.1551C>A p.S517R | Missense Mutation (SNP) | VAF 12/244 reads (5%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.975); called by muse, mutect2
- PLCG2 | c.3616C>T p.R1206W | Missense Mutation (SNP) | VAF 10/260 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.824); called by muse, mutect2
- PLEC | c.7886A>G p.Q2629R (on ENST00000322810 / NM_201380.4; = p.Q2519R on NM_000445.5) | Missense Mutation (SNP) | VAF 14/281 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.038); called by muse, mutect2
- PLEKHG2 | c.743A>C p.Q248P | Missense Mutation (SNP) | VAF 18/168 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- POLE | c.4850T>A p.I1617N | Missense Mutation (SNP) | VAF 16/335 reads (5%) | SIFT tolerated (0.49); PolyPhen benign (0.062); called by muse, mutect2
- PRAMEF7 | c.6C>A p.S2R | Missense Mutation (SNP) | VAF 12/198 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.02); called by muse, mutect2
- PRDM10 | c.776A>G p.K259R | Missense Mutation (SNP) | VAF 9/136 reads (7%) | SIFT tolerated (0.34); PolyPhen benign (0.392); called by muse, mutect2
- PRDX2 | c.409G>A p.V137I | Missense Mutation (SNP) | VAF 12/209 reads (6%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- PRPF18 | c.404A>T p.D135V | Missense Mutation (SNP) | VAF 13/328 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); called by muse, mutect2
- PRX | c.3923T>C p.L1308P | Missense Mutation (SNP) | VAF 22/448 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- PSMD13 | c.82C>T p.L28F | Missense Mutation (SNP) | VAF 17/347 reads (5%) | SIFT tolerated (0.37); PolyPhen benign (0.03); called by muse, mutect2
- PTCHD1 | c.1225G>A p.A409T | Missense Mutation (SNP) | VAF 19/407 reads (5%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.812); called by muse, mutect2
- PTPN9 | c.349C>T p.H117Y | Missense Mutation (SNP) | VAF 16/302 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2
- PTPRQ | c.1204G>A p.A402T (on ENST00000616559; = p.A360T on NM_001145026.2) | Missense Mutation (SNP) | VAF 17/280 reads (6%) | SIFT tolerated (0.59); PolyPhen benign (0.001); called by muse, mutect2
- PTPRZ1 | c.2774A>G p.E925G | Missense Mutation (SNP) | VAF 18/375 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.79); called by muse, mutect2
- PYCR1 | c.412G>T p.G138C | Missense Mutation (SNP) | VAF 27/425 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- PZP | c.2369C>T p.A790V | Missense Mutation (SNP) | VAF 21/282 reads (7%) | SIFT tolerated (1); PolyPhen benign (0.047); called by muse, mutect2
- RAI1 | c.2238G>A p.W746* | Nonsense Mutation (SNP) | VAF 16/415 reads (4%) | called by muse, mutect2
- RAPGEF2 | c.4225A>T p.I1409F | Missense Mutation (SNP) | VAF 12/248 reads (5%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.558); called by muse, mutect2
- REPS2 | c.209C>T p.A70V | Missense Mutation (SNP) | VAF 17/311 reads (5%) | SIFT tolerated (0.4); PolyPhen possibly damaging (0.768); called by muse, mutect2
- RHBDF2 | c.2351C>A p.A784D | Missense Mutation (SNP) | VAF 17/410 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.41); called by muse, mutect2
- RIMBP2 | c.2747C>A p.A916E | Missense Mutation (SNP) | VAF 15/334 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); called by muse, mutect2
- RIMS1 | c.176G>T p.R59M | Missense Mutation (SNP) | VAF 14/292 reads (5%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.054); called by muse, mutect2
- RNF111 | c.2868A>T p.R956S (on ENST00000557998 / NM_001270530.1; = p.R948S on NM_017610.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/170 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.048); called by muse, mutect2
- RNF170 | c.725T>C p.I242T | Missense Mutation (SNP) | VAF 8/182 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.541); called by muse, mutect2
- RNF215 | c.146_152del p.A49Gfs*14 | Frame Shift Del (DEL) | VAF 14/122 reads (11%) | called by mutect2, pindel
- RPTOR | c.1779G>A p.W593* | Nonsense Mutation (SNP) | VAF 18/388 reads (5%) | called by muse, mutect2
- RTN4RL2 | c.13C>A p.L5I | Missense Mutation (SNP) | VAF 21/354 reads (6%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.132); called by muse, mutect2
- RYR1 | c.3772C>T p.R1258* | Nonsense Mutation (SNP) | VAF 15/244 reads (6%) | called by muse, mutect2
- RYR1 | c.13057G>T p.G4353C | Missense Mutation (SNP) | VAF 11/286 reads (4%) | SIFT deleterious (0.04); PolyPhen benign (0.339); called by muse, mutect2
- SACS | c.10356T>G p.F3452L | Missense Mutation (SNP) | VAF 11/208 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2
- SCAF1 | c.1607C>T p.S536L | Missense Mutation (SNP) | VAF 20/330 reads (6%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.162); called by muse, mutect2
- SCN9A | c.5933A>G p.D1978G (on ENST00000303354; = p.D1967G on NM_002977.3) | Missense Mutation (SNP) | VAF 13/235 reads (6%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.014); called by muse, mutect2
- SEC14L3 | c.968T>C p.L323P | Missense Mutation (SNP) | VAF 16/370 reads (4%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.003); called by muse, mutect2
- SETD5 | c.525T>A p.S175R | Missense Mutation (SNP) | VAF 12/332 reads (4%) | SIFT tolerated (0.45); PolyPhen possibly damaging (0.654); called by muse, mutect2
- SEZ6 | c.2579C>T p.A860V | Missense Mutation (SNP) | VAF 24/414 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.243); called by muse, mutect2
- SIDT2 | c.848T>C p.L283P | Missense Mutation (SNP) | VAF 18/336 reads (5%) | SIFT tolerated (0.1); PolyPhen benign (0); called by muse, mutect2
- SIGLECL1 | c.172A>T p.T58S | Missense Mutation (SNP) | VAF 18/448 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.886); called by muse, mutect2
- SKOR2 | c.2726G>A p.G909E (on ENST00000425639 / NM_001278063.4; = p.E275K on NM_001037802.3) | Missense Mutation (SNP) | VAF 12/224 reads (5%) | SIFT deleterious, low confidence (0.05); called by muse, mutect2
- SLC14A2 | c.2452G>T p.A818S | Missense Mutation (SNP) | VAF 15/342 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.801); called by muse, mutect2
- SLC17A2 | c.137T>C p.V46A | Missense Mutation (SNP) | VAF 21/398 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); called by muse, mutect2
- SLC22A31 | c.551C>T p.T184I | Missense Mutation (SNP) | VAF 18/407 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); called by muse, mutect2
- SMC4 | c.725G>A p.G242D | Missense Mutation (SNP) | VAF 11/238 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2
- SOBP | c.1325G>T p.R442I | Missense Mutation (SNP) | VAF 24/417 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- SOX11 | c.1223G>A p.G408D | Missense Mutation (SNP) | VAF 20/384 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- SOX17 | c.473G>A p.G158D | Missense Mutation (SNP) | VAF 28/474 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.272); called by muse, mutect2
- SOX3 | c.377G>A p.G126D | Missense Mutation (SNP) | VAF 21/482 reads (4%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.638); called by muse, mutect2
- SPECC1 | c.1016C>A p.P339H | Missense Mutation (SNP) | VAF 12/330 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.886); called by muse, mutect2
- SPEN | c.8291G>A p.G2764E | Missense Mutation (SNP) | VAF 19/425 reads (4%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.261); called by muse, mutect2
- SPRED3 | c.788C>G p.T263S | Missense Mutation (SNP) | VAF 16/396 reads (4%) | SIFT tolerated (0.79); PolyPhen benign (0.026); called by muse, mutect2
- SPTBN4 | c.6667G>A p.A2223T | Missense Mutation (SNP) | VAF 24/482 reads (5%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.003); called by muse, mutect2
- SRRM3 | c.1427C>T p.A476V | Missense Mutation (SNP) | VAF 20/366 reads (5%) | SIFT tolerated (0.22); PolyPhen benign (0.003); called by muse, mutect2
- ST14 | c.2324C>T p.T775I | Missense Mutation (SNP) | VAF 26/364 reads (7%) | SIFT tolerated (0.12); PolyPhen benign (0.04); called by muse, mutect2
- STARD3 | c.983T>A p.L328H | Missense Mutation (SNP) | VAF 18/298 reads (6%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.954); called by muse, mutect2
- STPG3 | c.137G>A p.G46D | Missense Mutation (SNP) | VAF 12/285 reads (4%) | SIFT tolerated (0.18); PolyPhen benign (0.003); called by muse, mutect2
- STRIP1 | c.1417-1G>A p.X473_splice | Splice Site (SNP) | VAF 16/266 reads (6%) | called by muse, mutect2
- SUFU | c.895C>T p.R299* | Nonsense Mutation (SNP) | VAF 21/264 reads (8%) | called by muse, mutect2
- TAGAP | c.2084G>T p.R695M | Missense Mutation (SNP) | VAF 30/403 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.95); called by muse, mutect2
- TANC2 | c.3826A>G p.R1276G | Missense Mutation (SNP) | VAF 16/354 reads (5%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); called by muse, mutect2
- TAP2 | c.850T>G p.F284V | Missense Mutation (SNP) | VAF 30/549 reads (5%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); called by muse, mutect2
- TAP2 | c.631G>T p.G211* | Nonsense Mutation (SNP) | VAF 19/334 reads (6%) | called by muse, mutect2
- TBC1D31 | c.1032G>T p.K344N | Missense Mutation (SNP) | VAF 6/124 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.249); called by muse, mutect2
- TBX19 | c.1058A>G p.Y353C | Missense Mutation (SNP) | VAF 11/254 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- TCEAL7 | c.93G>T p.Q31H | Missense Mutation (SNP) | VAF 19/413 reads (5%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.963); called by muse, mutect2
- TCP11L1 | c.772C>T p.P258S | Missense Mutation (SNP) | VAF 12/227 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.691); called by muse, mutect2
- TELO2 | c.512T>C p.L171P | Missense Mutation (SNP) | VAF 23/406 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); called by muse, mutect2
- TENM4 | c.3323C>T p.A1108V | Missense Mutation (SNP) | VAF 16/424 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2
- TFAP2B | c.1205C>T p.T402M | Missense Mutation (SNP) | VAF 16/380 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- TIMP3 | c.31C>A p.L11M | Missense Mutation (SNP) | VAF 14/284 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.969); called by muse, mutect2
- TMC3 | c.3131T>C p.V1044A | Missense Mutation (SNP) | VAF 16/391 reads (4%) | SIFT tolerated, low confidence (0.77); PolyPhen benign (0.003); called by muse, mutect2
- TMEM217 | c.155C>T p.A52V | Missense Mutation (SNP) | VAF 15/345 reads (4%) | SIFT tolerated (0.38); PolyPhen benign (0.023); called by muse, mutect2
- TMEM259 | c.1634C>T p.A545V | Missense Mutation (SNP) | VAF 31/499 reads (6%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.914); called by muse, mutect2
- TNFAIP2 | c.814C>T p.R272C | Missense Mutation (SNP) | VAF 16/349 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); called by muse, mutect2
- TNFRSF19 | c.491G>A p.S164N | Missense Mutation (SNP) | VAF 18/362 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- TNFRSF1A | c.1156G>A p.D386N | Missense Mutation (SNP) | VAF 22/542 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.511); called by muse, mutect2
- TP53BP1 | c.2195C>T p.A732V | Missense Mutation (SNP) | VAF 14/360 reads (4%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.001); called by muse, mutect2
- TPMT | c.284G>T p.G95V | Missense Mutation (SNP) | VAF 10/238 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.852); called by muse, mutect2
- TRPA1 | c.2483C>T p.A828V | Missense Mutation (SNP) | VAF 26/477 reads (5%) | SIFT tolerated (0.18); PolyPhen benign (0.038); called by muse, mutect2
- TTLL5 | c.1287C>A p.C429* | Nonsense Mutation (SNP) | VAF 10/187 reads (5%) | called by muse, mutect2
- TTN | c.44587C>T p.P14863S (on ENST00000591111; = p.P7439S on NM_003319.4) | Missense Mutation (SNP) | VAF 8/208 reads (4%) | PolyPhen probably damaging (0.998); called by muse, mutect2
- TTN | c.29165A>G p.E9722G (on ENST00000591111; = p.E8795G on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/362 reads (4%) | PolyPhen benign (0.036); called by muse, mutect2
- TYR | c.1035A>G p.E345= | Splice Region (SNP) | VAF 8/154 reads (5%) | called by muse, mutect2
- UAP1L1 | c.487G>A p.V163I | Missense Mutation (SNP) | VAF 16/288 reads (6%) | SIFT tolerated (1); PolyPhen benign (0.02); called by muse, mutect2
- UBN1 | c.944A>G p.D315G | Missense Mutation (SNP) | VAF 14/330 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); called by muse, mutect2
- UGT2B11 | c.512G>A p.S171N | Missense Mutation (SNP) | VAF 13/336 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.378); called by muse, mutect2
- UNK | c.677G>A p.R226Q | Missense Mutation (SNP) | VAF 14/407 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2
- USP39 | c.1082C>A p.P361H | Missense Mutation (SNP) | VAF 18/330 reads (5%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.902); called by muse, mutect2
- VASH2 | c.493G>A p.G165S (on ENST00000517399 / NM_001301056.2; = p.G100S on NM_001136474.3) | Missense Mutation (SNP) | VAF 13/266 reads (5%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.984); called by muse, mutect2
- VN1R1 | c.1060T>C p.*354Rext*18 | Nonstop Mutation (SNP) | VAF 11/164 reads (7%) | called by muse, mutect2
- VSTM4 | c.41G>A p.R14Q | Missense Mutation (SNP) | VAF 13/185 reads (7%) | SIFT tolerated (0.31); PolyPhen benign (0.014); called by muse, mutect2
- WDTC1 | c.1643G>T p.S548I (on ENST00000319394 / NM_001276252.2; = p.S547I on NM_015023.5) | Missense Mutation (SNP) | VAF 18/177 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.919); called by muse, mutect2
- WIPF2 | c.570del p.T191Hfs*47 | Frame Shift Del (DEL) | VAF 25/244 reads (10%) | called by mutect2, pindel
- YTHDF3 | c.694G>A p.A232T | Missense Mutation (SNP) | VAF 16/358 reads (4%) | SIFT tolerated (0.32); PolyPhen benign (0.007); called by muse, mutect2
- ZBED3 | c.485G>A p.R162H | Missense Mutation (SNP) | VAF 18/326 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.94); called by muse, mutect2
- ZFHX2 | c.6394A>G p.S2132G | Missense Mutation (SNP) | VAF 19/385 reads (5%) | SIFT tolerated (0.6); PolyPhen benign (0); called by muse, mutect2
- ZFP14 | c.1424C>T p.T475I | Missense Mutation (SNP) | VAF 16/369 reads (4%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); called by muse, mutect2
- ZGRF1 | c.715G>A p.A239T | Missense Mutation (SNP) | VAF 10/264 reads (4%) | SIFT tolerated (0.5); PolyPhen benign (0.001); called by muse, mutect2
- ZMYM3 | c.3136G>A p.E1046K | Missense Mutation (SNP) | VAF 18/366 reads (5%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.736); called by muse, mutect2
- ZNF112 | c.1364C>T p.A455V (on ENST00000337401 / NM_001083335.2; = p.A449V on NM_013380.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 15/386 reads (4%) | SIFT deleterious (0.03); PolyPhen benign (0); called by muse, mutect2
- ZNF205 | c.938G>A p.C313Y | Missense Mutation (SNP) | VAF 20/392 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- ZNF469 | c.3290A>G p.E1097G (on ENST00000437464; = p.E1125G on NM_001367624.2) | Missense Mutation (SNP) | VAF 17/434 reads (4%) | SIFT tolerated (0.22); PolyPhen benign (0); called by muse, mutect2
- ZNF629 | c.757C>A p.Q253K | Missense Mutation (SNP) | VAF 26/389 reads (7%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.955); called by muse, mutect2
- ZNF699 | c.286+1G>A p.X96_splice | Splice Site (SNP) | VAF 10/228 reads (4%) | called by muse, mutect2
- ZNF70 | c.510C>A p.C170* | Nonsense Mutation (SNP) | VAF 26/505 reads (5%) | called by muse, mutect2
- ZNF710 | c.1465A>G p.K489E | Missense Mutation (SNP) | VAF 12/230 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- ZNF768 | c.1196G>T p.R399M | Missense Mutation (SNP) | VAF 22/450 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.979); called by muse, mutect2
- ZNF99 | c.481A>C p.N161H | Missense Mutation (SNP) | VAF 8/146 reads (5%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.978); called by muse, mutect2
- ABCB11 | c.2703C>T p.S901= | Silent (SNP) | VAF 18/508 reads (4%) | catalogued as rs1421685722, CM110927, COSV55597892; called by muse, mutect2
- ABCC6 | c.3384T>C p.A1128= | Silent (SNP) | VAF 24/568 reads (4%) | called by muse, mutect2
- ABCG4 | c.1254C>T p.S418= | Silent (SNP) | VAF 16/423 reads (4%) | called by muse, mutect2
- ADAMTSL5 | c.1200C>T p.R400= | Silent (SNP) | VAF 18/470 reads (4%) | called by muse, mutect2
- ADCY8 | c.69G>A p.P23= | Silent (SNP) | VAF 20/374 reads (5%) | called by muse, mutect2
- ADGB | c.1140A>G p.K380= | Silent (SNP) | VAF 21/269 reads (8%) | catalogued as rs1305993283; called by muse, mutect2
- ADGB | c.3648G>A p.K1216= | Silent (SNP) | VAF 26/359 reads (7%) | called by muse, mutect2
- ADRA1D | c.927C>T p.R309= | Silent (SNP) | VAF 22/468 reads (5%) | called by muse, mutect2
- AKAP17A | c.1269C>T p.R423= | Silent (SNP) | VAF 28/526 reads (5%) | catalogued as rs751396392, COSV58308355; called by muse, mutect2
- AMER2 | c.63G>A p.A21= | Silent (SNP) | VAF 18/392 reads (5%) | catalogued as rs1177219493, COSV63435968; called by muse, mutect2
- ANGEL2 | c.297C>T p.N99= | Silent (SNP) | VAF 14/276 reads (5%) | called by muse, mutect2
- ANK2 | c.2157T>C p.A719= | Silent (SNP) | VAF 12/245 reads (5%) | called by muse, mutect2
- APC2 | c.1179C>T p.G393= | Silent (SNP) | VAF 14/384 reads (4%) | catalogued as rs1390010724; called by muse, mutect2
- ASTN1 | c.3591G>A p.Q1197= | Silent (SNP) | VAF 18/330 reads (5%) | catalogued as COSV62500449; called by muse, mutect2
- B3GNT9 | c.294G>A p.L98= | Silent (SNP) | VAF 19/360 reads (5%) | called by muse, mutect2
- BCL2L12 | c.822G>A p.P274= | Silent (SNP) | VAF 16/504 reads (3%) | catalogued as rs1417871655; called by muse, mutect2
- BCL9L | c.4104G>A p.E1368= | Silent (SNP) | VAF 20/460 reads (4%) | called by muse, mutect2
- BEST1 | c.1686C>T p.N562= | Silent (SNP) | VAF 18/352 reads (5%) | called by muse, mutect2
- BEST4 | c.1008C>T p.S336= | Silent (SNP) | VAF 17/265 reads (6%) | called by muse, mutect2
- BLOC1S3 | c.483C>A p.R161= | Silent (SNP) | VAF 22/396 reads (6%) | called by muse, mutect2
- C17orf107 | c.108C>T p.S36= | Silent (SNP) | VAF 15/299 reads (5%) | called by muse, mutect2
- CACNA1A | c.903C>T p.F301= | Silent (SNP) | VAF 29/405 reads (7%) | catalogued as rs17846910, CM1410176; ClinVar: likely benign; called by muse, mutect2
- CACNA2D3 | c.1164A>G p.R388= | Silent (SNP) | VAF 10/201 reads (5%) | called by muse, mutect2
- CAPN15 | c.444G>A p.A148= | Silent (SNP) | VAF 28/440 reads (6%) | catalogued as rs761835704; called by muse, mutect2
- CD4 | c.510C>T p.S170= | Silent (SNP) | VAF 19/358 reads (5%) | catalogued as rs143618857; called by muse, mutect2
- CD6 | c.1956T>C p.P652= | Silent (SNP) | VAF 16/340 reads (5%) | called by muse, mutect2
- CENPB | c.1044G>A p.A348= | Silent (SNP) | VAF 26/467 reads (6%) | catalogued as COSV60148691; called by muse, mutect2
- CHRNB1 | c.51C>T p.L17= | Silent (SNP) | VAF 22/370 reads (6%) | catalogued as rs1351230064; ClinVar: likely benign; called by muse, mutect2
- COL18A1 | c.2730C>T p.P910= (on ENST00000359759 / NM_130444.3; = p.P675= on NM_030582.4) | Silent (SNP) | VAF 12/324 reads (4%) | catalogued as COSV100700619; called by muse, mutect2
- CRACD | c.2034C>T p.N678= | Silent (SNP) | VAF 17/361 reads (5%) | catalogued as rs1395382142, COSV51719893; called by muse, mutect2
- CSF2RB | c.516G>A p.E172= | Silent (SNP) | VAF 16/312 reads (5%) | called by muse, mutect2
- CTNND2 | c.1104G>A p.A368= | Silent (SNP) | VAF 16/478 reads (3%) | called by muse, mutect2
- DACT2 | c.1632C>T p.G544= | Silent (SNP) | VAF 53/583 reads (9%) | catalogued as rs370614642; called by muse, mutect2
- DDX46 | c.1224T>C p.S408= | Silent (SNP) | VAF 14/238 reads (6%) | called by muse, mutect2
- DONSON | c.1665G>T p.V555= | Silent (SNP) | VAF 15/238 reads (6%) | called by muse, mutect2
- DPP9 | c.2004C>A p.A668= (on ENST00000598800; = p.A697= on NM_139159.5) | Silent (SNP) | VAF 23/432 reads (5%) | called by muse, mutect2
- EEF2 | c.1821G>A p.R607= | Silent (SNP) | VAF 18/388 reads (5%) | called by muse, mutect2
- EPHA5 | c.429A>G p.G143= | Silent (SNP) | VAF 18/332 reads (5%) | called by muse, mutect2
- ERFE | c.519C>T p.T173= | Silent (SNP) | VAF 30/436 reads (7%) | catalogued as rs1431828349, COSV100621274; called by muse, mutect2
- ERRFI1 | c.307T>C p.L103= | Silent (SNP) | VAF 19/364 reads (5%) | called by muse, mutect2
- EVPL | c.510G>A p.P170= | Silent (SNP) | VAF 14/298 reads (5%) | catalogued as rs1464294203, COSV56907043; called by muse, mutect2
- EXD3 | c.1230C>G p.G410= | Silent (SNP) | VAF 19/404 reads (5%) | called by muse, mutect2
- FAM120B | c.1599T>C p.P533= | Silent (SNP) | VAF 48/433 reads (11%) | catalogued as rs771307652; called by muse, mutect2
- FAM174C | c.6G>A p.G2= | Silent (SNP) | VAF 12/234 reads (5%) | called by muse, mutect2
- FAT1 | c.6186G>A p.V2062= | Silent (SNP) | VAF 20/358 reads (6%) | called by muse, mutect2
- FBLL1 | c.537C>T p.G179= | Silent (SNP) | VAF 23/351 reads (7%) | called by muse, mutect2
- FITM2 | c.687C>T p.S229= | Silent (SNP) | VAF 18/313 reads (6%) | called by muse, mutect2
- FIZ1 | c.894G>A p.A298= | Silent (SNP) | VAF 21/401 reads (5%) | called by muse, mutect2
- FLNC | c.2484C>A p.T828= | Silent (SNP) | VAF 25/357 reads (7%) | called by muse, mutect2
- FNDC8 | c.774C>T p.V258= | Silent (SNP) | VAF 20/274 reads (7%) | catalogued as COSV50102434; called by muse, mutect2
- FOXQ1 | c.1107C>T p.G369= | Silent (SNP) | VAF 14/340 reads (4%) | catalogued as rs1188270493; called by muse, mutect2
- FSIP2 | c.15309C>T p.S5103= | Silent (SNP) | VAF 10/232 reads (4%) | called by muse, mutect2
- FTCD | c.343C>T p.L115= | Silent (SNP) | VAF 18/397 reads (5%) | catalogued as rs772011871; called by muse, mutect2
- FTCD | c.162G>A p.P54= | Silent (SNP) | VAF 29/529 reads (5%) | catalogued as rs759113890; called by muse, mutect2
- FZD2 | c.510G>A p.P170= | Silent (SNP) | VAF 14/258 reads (5%) | catalogued as rs1057399025; called by muse, mutect2
- GATA6 | c.1734C>T p.A578= | Silent (SNP) | VAF 22/380 reads (6%) | catalogued as rs747397185, COSV52526601; called by muse, mutect2
- GFRA2 | c.1245C>T p.S415= | Silent (SNP) | VAF 15/379 reads (4%) | called by muse, mutect2
- GPC2 | c.492G>A p.A164= | Silent (SNP) | VAF 24/380 reads (6%) | catalogued as rs746634939, COSV52786539; called by muse, mutect2
- GPR142 | c.120C>A p.S40= | Silent (SNP) | VAF 28/337 reads (8%) | called by muse, mutect2
- GPR37 | c.225G>A p.E75= | Silent (SNP) | VAF 18/410 reads (4%) | called by muse, mutect2
- GPR88 | c.531G>A p.P177= | Silent (SNP) | VAF 25/426 reads (6%) | catalogued as rs966876869; called by muse, mutect2
- GPX4 | c.283T>C p.L95= | Silent (SNP) | VAF 20/336 reads (6%) | called by muse, mutect2
- HAPLN2 | c.873C>T p.D291= | Silent (SNP) | VAF 24/484 reads (5%) | called by muse, mutect2
- HARBI1 | c.273T>C p.D91= | Silent (SNP) | VAF 14/357 reads (4%) | called by muse, mutect2
- HNRNPF | c.315C>T p.A105= | Silent (SNP) | VAF 16/406 reads (4%) | catalogued as rs1289161733; called by muse, mutect2
- HOXD12 | c.777C>T p.R259= | Silent (SNP) | VAF 15/380 reads (4%) | catalogued as COSV66832562; called by muse, mutect2
- IFFO2 | c.597G>A p.T199= | Silent (SNP) | VAF 18/352 reads (5%) | called by muse, mutect2
- IGSF9B | c.1932C>T p.I644= | Silent (SNP) | VAF 28/383 reads (7%) | catalogued as rs765113689, COSV58072654; called by muse, mutect2
- IL17RE | c.1506G>A p.R502= | Silent (SNP) | VAF 22/406 reads (5%) | called by muse, mutect2
- INPP5D | c.3444G>A p.P1148= (on ENST00000445964 / NM_001017915.3; = p.P1147= on NM_005541.5) | Silent (SNP) | VAF 18/402 reads (4%) | catalogued as rs766322758; called by muse, mutect2
- INSM2 | c.642G>A p.A214= | Silent (SNP) | VAF 34/433 reads (8%) | catalogued as rs776877072; called by muse, mutect2
- ISYNA1 | c.483G>T p.L161= | Silent (SNP) | VAF 34/392 reads (9%) | called by muse, mutect2
- JRK | c.249G>A p.T83= | Silent (SNP) | VAF 30/432 reads (7%) | catalogued as rs1426737695, COSV70630493; called by muse, mutect2
- JSRP1 | c.213C>T p.A71= | Silent (SNP) | VAF 18/396 reads (5%) | catalogued as rs1471733711, COSV55558185, COSV99678382; called by muse, mutect2
- KCMF1 | c.357C>T p.G119= | Silent (SNP) | VAF 11/302 reads (4%) | catalogued as COSV69054820; called by muse, mutect2
- KCNK13 | c.81C>T p.I27= | Silent (SNP) | VAF 18/336 reads (5%) | catalogued as rs1409401164; called by muse, mutect2
- KIF26B | c.4935G>A p.T1645= | Silent (SNP) | VAF 30/578 reads (5%) | catalogued as rs201949312; called by muse, mutect2
- KIF5B | c.1029G>A p.K343= | Silent (SNP) | VAF 20/258 reads (8%) | called by muse, mutect2
- KLHDC7B | c.282G>A p.P94= (on ENST00000395676; = p.P735= on NM_138433.5) | Silent (SNP) | VAF 30/512 reads (6%) | called by muse, mutect2
- KMT2C | c.3639C>T p.S1213= | Silent (SNP) | VAF 28/366 reads (8%) | catalogued as rs761630870, COSV51445452; called by muse, mutect2
- KRTAP12-3 | c.123G>A p.T41= | Silent (SNP) | VAF 24/484 reads (5%) | catalogued as rs782250308, COSV59976125; called by muse, mutect2
- KRTAP17-1 | c.159C>T p.C53= | Silent (SNP) | VAF 24/460 reads (5%) | catalogued as rs753404980, COSV100498545; called by muse, mutect2
- LAMB2 | c.2775G>A p.R925= | Silent (SNP) | VAF 20/506 reads (4%) | called by muse, mutect2
- LENG8 | c.1137G>A p.P379= | Silent (SNP) | VAF 26/590 reads (4%) | catalogued as rs373827414; called by muse, mutect2
- LOXL1 | c.78G>A p.Q26= | Silent (SNP) | VAF 18/376 reads (5%) | catalogued as rs1296832593; called by muse, mutect2
- LPCAT2 | c.825C>T p.C275= | Silent (SNP) | VAF 11/242 reads (5%) | catalogued as rs1376111230; called by muse, mutect2
- LPP | c.1560G>A p.G520= | Silent (SNP) | VAF 16/320 reads (5%) | catalogued as COSV100446043; called by muse, mutect2
- LRP10 | c.69T>C p.F23= | Silent (SNP) | VAF 16/326 reads (5%) | called by muse, mutect2
- LRRK1 | c.1056A>G p.S352= | Silent (SNP) | VAF 14/238 reads (6%) | called by muse, mutect2
- MAP4K2 | c.2310T>C p.D770= | Silent (SNP) | VAF 12/248 reads (5%) | called by muse, mutect2
- MARCHF4 | c.276C>G p.G92= | Silent (SNP) | VAF 24/422 reads (6%) | catalogued as rs897467831; called by muse, mutect2
- MAST1 | c.3735C>T p.V1245= | Silent (SNP) | VAF 26/430 reads (6%) | catalogued as rs1368482983; called by muse, mutect2
- MCM3AP | c.246A>G p.G82= | Silent (SNP) | VAF 17/380 reads (4%) | called by muse, mutect2
- MCOLN1 | c.1458C>T p.R486= | Silent (SNP) | VAF 22/360 reads (6%) | called by muse, mutect2
- MDGA1 | c.1641C>T p.D547= | Silent (SNP) | VAF 16/318 reads (5%) | catalogued as rs946258328, COSV51798689; called by muse, mutect2
- MFSD4A | c.732G>A p.E244= | Silent (SNP) | VAF 12/342 reads (4%) | called by muse, mutect2
- MMP25 | c.1035C>T p.S345= | Silent (SNP) | VAF 26/363 reads (7%) | called by muse, mutect2
- MROH6 | c.574C>T p.L192= | Silent (SNP) | VAF 16/377 reads (4%) | called by muse, mutect2
- MTLN | c.153C>T p.F51= | Silent (SNP) | VAF 16/308 reads (5%) | catalogued as rs1263543398; called by muse, mutect2
- MUC5B | c.15843C>A p.T5281= | Silent (SNP) | VAF 21/278 reads (8%) | called by muse, mutect2
- MYOZ1 | c.618G>A p.L206= | Silent (SNP) | VAF 18/328 reads (5%) | called by muse, mutect2
- MYT1 | c.663C>T p.A221= | Silent (SNP) | VAF 20/546 reads (4%) | catalogued as rs767800045; called by muse, mutect2
- NECAB1 | c.24G>A p.S8= | Silent (SNP) | VAF 21/294 reads (7%) | called by muse, mutect2
- NEUROG2 | c.297C>T p.G99= | Silent (SNP) | VAF 12/344 reads (3%) | called by muse, mutect2
- NKAIN4 | c.348T>C p.H116= | Silent (SNP) | VAF 24/454 reads (5%) | called by muse, mutect2
- NKPD1 | c.1194G>A p.S398= | Silent (SNP) | VAF 14/324 reads (4%) | called by muse, mutect2
- NPHP4 | c.1728G>A p.L576= | Silent (SNP) | VAF 12/342 reads (4%) | called by muse, mutect2
- NRG3 | c.525C>A p.I175= | Silent (SNP) | VAF 24/518 reads (5%) | catalogued as COSV100931774, COSV64560367; called by muse, mutect2
- OLFM1 | c.318C>T p.G106= | Silent (SNP) | VAF 14/359 reads (4%) | catalogued as rs1245689317; called by muse, mutect2
- OLFM1 | c.237T>C p.S79= | Silent (SNP) | VAF 20/366 reads (5%) | called by muse, mutect2
- OR1R1P | c.717C>T p.C239= | Silent (SNP) | VAF 23/323 reads (7%) | catalogued as rs1177162814; called by muse, mutect2
- OR4D9 | c.171G>A p.T57= | Silent (SNP) | VAF 15/403 reads (4%) | catalogued as rs1451512271, COSV61435763; called by muse, mutect2
- OR4K13 | c.456A>T p.G152= | Silent (SNP) | VAF 18/370 reads (5%) | called by muse, mutect2
- P3H4 | c.396G>A p.P132= | Silent (SNP) | VAF 17/358 reads (5%) | called by muse, mutect2
- PAQR8 | c.582T>C p.C194= | Silent (SNP) | VAF 15/390 reads (4%) | called by muse, mutect2
- PCDHA3 | c.1119C>T p.S373= | Silent (SNP) | VAF 15/325 reads (5%) | catalogued as rs782601468, COSV63538789; called by muse, mutect2
- PCDHB6 | c.630G>A p.T210= | Silent (SNP) | VAF 24/438 reads (5%) | catalogued as COSV50700151; called by muse, mutect2
- PCDHGB1 | c.1635C>T p.R545= | Silent (SNP) | VAF 22/482 reads (5%) | catalogued as COSV54034813; called by muse, mutect2
- PCDHGB7 | c.1872C>T p.G624= | Silent (SNP) | VAF 18/394 reads (5%) | called by muse, mutect2
- PHGDH | c.1587A>G p.A529= (on ENST00000369409; = p.Q523R on NM_006623.4) | Silent (SNP) | VAF 18/376 reads (5%) | called by muse, mutect2
- PKD1 | c.6831T>C p.D2277= | Silent (SNP) | VAF 11/308 reads (4%) | called by muse, mutect2
- PLEC | c.12330C>T p.T4110= (on ENST00000322810 / NM_201380.4; = p.T4000= on NM_000445.5) | Silent (SNP) | VAF 21/398 reads (5%) | catalogued as rs373493332; called by muse, mutect2
- PLXND1 | c.5538G>A p.T1846= | Silent (SNP) | VAF 29/336 reads (9%) | catalogued as rs778694584, COSV60715083; called by muse, mutect2
- PNLIPRP2 | c.522G>A p.A174= | Silent (SNP) | VAF 18/327 reads (6%) | catalogued as rs1554869138; called by muse, mutect2
- POC1B-GALNT4 | c.1191A>G p.P397= | Silent (SNP) | VAF 14/294 reads (5%) | called by muse, mutect2
- PPIL4 | c.750G>A p.V250= | Silent (SNP) | VAF 22/284 reads (8%) | called by muse, mutect2
- PRDM14 | c.582G>A p.R194= | Silent (SNP) | VAF 17/449 reads (4%) | called by muse, mutect2
- PROKR1 | c.651C>T p.C217= | Silent (SNP) | VAF 20/364 reads (5%) | catalogued as rs1214541096, COSV58137888; called by muse, mutect2
- PRRT4 | c.1848G>A p.A616= | Silent (SNP) | VAF 27/463 reads (6%) | catalogued as rs1242180512; called by muse, mutect2
- PSMD2 | c.2376C>A p.A792= | Silent (SNP) | VAF 18/375 reads (5%) | called by muse, mutect2
- RASAL3 | c.1086G>A p.P362= | Silent (SNP) | VAF 20/390 reads (5%) | called by muse, mutect2
- RBFOX1 | c.213G>A p.T71= | Silent (SNP) | VAF 20/352 reads (6%) | catalogued as rs1433814435, COSV60958631; called by muse, mutect2
- RBM15B | c.879C>T p.A293= | Silent (SNP) | VAF 24/536 reads (4%) | called by muse, mutect2
- RBMXL3 | c.2049C>T p.G683= | Silent (SNP) | VAF 28/586 reads (5%) | called by muse, mutect2
- RNASET2 | c.642C>T p.T214= | Silent (SNP) | VAF 27/376 reads (7%) | catalogued as rs201960492; called by muse, mutect2
- ROBO1 | c.583C>A p.R195= | Silent (SNP) | VAF 22/391 reads (6%) | catalogued as COSV71394851; called by muse, mutect2
- RPRM | c.78C>T p.A26= | Silent (SNP) | VAF 18/408 reads (4%) | catalogued as COSV57989016; called by muse, mutect2
- RREB1 | c.4155C>T p.G1385= | Silent (SNP) | VAF 16/355 reads (5%) | catalogued as rs1165958122, COSV58564883; called by muse, mutect2
- S1PR5 | c.748C>T p.L250= | Silent (SNP) | VAF 40/454 reads (9%) | catalogued as rs745900303; called by muse, mutect2
- SARM1 | c.261C>T p.A87= | Silent (SNP) | VAF 26/436 reads (6%) | catalogued as rs1028371121; called by muse, mutect2
- SART3 | c.2616G>A p.A872= (on ENST00000228284; = p.A854= on NM_014706.4) | Silent (SNP) | VAF 14/289 reads (5%) | catalogued as rs925334839, COSV57206344; called by muse, mutect2
- SCUBE1 | c.411C>T p.G137= | Silent (SNP) | VAF 20/391 reads (5%) | called by muse, mutect2
- SECISBP2L | c.444T>C p.T148= | Silent (SNP) | VAF 18/352 reads (5%) | called by muse, mutect2
- SEMA5B | c.1404C>T p.S468= | Silent (SNP) | VAF 16/391 reads (4%) | catalogued as rs1384943155, COSV52098841; called by muse, mutect2
- SEZ6L | c.2292G>A p.V764= | Silent (SNP) | VAF 18/388 reads (5%) | called by muse, mutect2
- SHC3 | c.1479A>G p.E493= | Silent (SNP) | VAF 26/376 reads (7%) | called by muse, mutect2
- SKOR1 | c.1101C>T p.A367= | Silent (SNP) | VAF 16/402 reads (4%) | catalogued as COSV58250588; called by muse, mutect2
- SLC16A8 | c.624C>T p.S208= | Silent (SNP) | VAF 22/350 reads (6%) | called by muse, mutect2
- SLC20A2 | c.954C>T p.T318= | Silent (SNP) | VAF 12/198 reads (6%) | called by muse, mutect2
- SLC25A23 | c.1350C>T p.S450= | Silent (SNP) | VAF 23/345 reads (7%) | called by muse, mutect2
- SLC25A26 | c.15G>A p.G5= | Silent (SNP) | VAF 14/303 reads (5%) | called by muse, mutect2
- SLC2A2 | c.1290A>G p.G430= | Silent (SNP) | VAF 15/348 reads (4%) | called by muse, mutect2
- SLC41A2 | c.1338T>C p.P446= | Silent (SNP) | VAF 12/250 reads (5%) | called by muse, mutect2
- SLC8A2 | c.1494C>T p.G498= | Silent (SNP) | VAF 24/458 reads (5%) | called by muse, mutect2
- SLITRK4 | c.2037T>C p.D679= | Silent (SNP) | VAF 19/402 reads (5%) | called by muse, mutect2
- SMPD2 | c.1005G>A p.L335= | Silent (SNP) | VAF 26/414 reads (6%) | catalogued as rs1442844442; called by muse, mutect2
- SOGA3 | c.2247C>T p.R749= | Silent (SNP) | VAF 16/418 reads (4%) | catalogued as COSV64105565; called by muse, mutect2
- SPEN | c.4995G>A p.A1665= | Silent (SNP) | VAF 16/344 reads (5%) | catalogued as rs906062557, COSV65360727; called by muse, mutect2
- SPINK4 | c.84G>A p.K28= | Silent (SNP) | VAF 22/287 reads (8%) | called by muse, mutect2
- SPON2 | c.408G>A p.T136= | Silent (SNP) | VAF 20/378 reads (5%) | catalogued as rs1446120183; called by muse, mutect2
- STAT2 | c.903C>T p.N301= | Silent (SNP) | VAF 20/302 reads (7%) | catalogued as rs145152331; ClinVar: likely benign; called by muse, mutect2
- STOX1 | c.1095T>C p.I365= | Silent (SNP) | VAF 20/354 reads (6%) | called by muse, mutect2
- SYNE1 | c.13791G>A p.E4597= (on ENST00000367255 / NM_182961.4; = p.E4526= on NM_033071.3) | Silent (SNP) | VAF 22/314 reads (7%) | called by muse, mutect2
- SYNM | c.3525G>A p.T1175= | Silent (SNP) | VAF 14/364 reads (4%) | catalogued as rs782117342; called by muse, mutect2
- SYPL2 | c.792T>C p.A264= | Silent (SNP) | VAF 24/411 reads (6%) | called by muse, mutect2
- TAF1L | c.3454C>T p.L1152= | Silent (SNP) | VAF 17/372 reads (5%) | called by muse, mutect2
- TAZ | c.39G>A p.P13= | Silent (SNP) | VAF 14/306 reads (5%) | catalogued as rs1557190864, COSV99186351; called by muse, mutect2
- TCF7L2 | c.909G>A p.T303= (on ENST00000355995 / NM_001367943.1; = p.T280= on NM_030756.5) | Silent (SNP) | VAF 18/450 reads (4%) | catalogued as rs1418521310, COSV53339121; called by muse, mutect2
- TCOF1 | c.1884T>A p.T628= (on ENST00000377797 / NM_001135243.1; = p.T551= on NM_000356.4) | Silent (SNP) | VAF 22/267 reads (8%) | called by muse, mutect2
- TLR7 | c.429G>A p.P143= | Silent (SNP) | VAF 28/546 reads (5%) | catalogued as rs1341054327, COSV66125842; called by muse, mutect2
- TMEM247 | c.228C>T p.C76= | Silent (SNP) | VAF 18/368 reads (5%) | called by muse, mutect2
- TNKS1BP1 | c.1926G>A p.Q642= | Silent (SNP) | VAF 14/387 reads (4%) | catalogued as rs1018370051; called by muse, mutect2
- TOR4A | c.75C>A p.P25= | Silent (SNP) | VAF 20/416 reads (5%) | called by muse, mutect2
- TPBG | c.504C>T p.S168= | Silent (SNP) | VAF 14/415 reads (3%) | catalogued as rs1285772483; called by muse, mutect2
- TRAK2 | c.2148C>A p.S716= | Silent (SNP) | VAF 18/352 reads (5%) | called by muse, mutect2
- TRIM10 | c.297C>T p.C99= | Silent (SNP) | VAF 41/620 reads (7%) | catalogued as COSV64989079; called by muse, mutect2
- TRIP11 | c.549A>G p.R183= | Silent (SNP) | VAF 15/234 reads (6%) | called by muse, mutect2
- TRIP12 | c.5254C>T p.L1752= | Silent (SNP) | VAF 21/372 reads (6%) | called by muse, mutect2
- TTLL13P | c.1635T>C p.A545= | Silent (SNP) | VAF 20/420 reads (5%) | catalogued as rs1243372135; called by muse, mutect2
- TUBB6 | c.1062C>T p.C354= | Silent (SNP) | VAF 26/486 reads (5%) | catalogued as rs1290653609, COSV52316693; called by muse, mutect2
- TUBGCP6 | c.2916T>C p.A972= | Silent (SNP) | VAF 16/352 reads (5%) | called by muse, mutect2
- TUT4 | c.1455C>A p.A485= | Silent (SNP) | VAF 18/346 reads (5%) | called by muse, mutect2
- UBQLNL | c.306C>T p.S102= | Silent (SNP) | VAF 20/398 reads (5%) | called by muse, mutect2
- UBR4 | c.6471C>T p.G2157= | Silent (SNP) | VAF 16/226 reads (7%) | catalogued as COSV64389161, COSV64392326; called by muse, mutect2
- VWA3B | c.2448T>C p.A816= | Silent (SNP) | VAF 13/237 reads (5%) | called by muse, mutect2
- WNT3 | c.552G>A p.S184= | Silent (SNP) | VAF 16/406 reads (4%) | catalogued as rs769539558; called by muse, mutect2
- ZNF213 | c.624A>G p.P208= | Silent (SNP) | VAF 11/254 reads (4%) | called by muse, mutect2
- ZNF385B | c.72C>T p.G24= | Silent (SNP) | VAF 22/428 reads (5%) | called by muse, mutect2
- ZNF516 | c.966C>A p.V322= | Silent (SNP) | VAF 20/422 reads (5%) | catalogued as COSV71587491; called by muse, mutect2
- ZNF778 | c.945A>G p.G315= | Silent (SNP) | VAF 15/327 reads (5%) | called by muse, mutect2
- ARHGEF4 | chr2:130916515 C>T | 5'Flank (SNP) | VAF 27/429 reads (6%) | called by muse, mutect2
- ATP6V1G2 | chr6:31548402 C>T | 5'Flank (SNP) | VAF 19/471 reads (4%) | catalogued as rs1280045382, COSV100385504; called by muse, mutect2
- C8orf86 | n.1069C>A | RNA (SNP) | VAF 12/280 reads (4%) | called by muse, mutect2
- CA6 | c.845-216A>G | Intron (SNP) | VAF 18/265 reads (7%) | called by muse, mutect2
- FBRSL1 | c.489+1576C>T | Intron (SNP) | VAF 26/470 reads (6%) | catalogued as rs1424127236; called by muse, mutect2
- FBRSL1 | c.489+1896C>T | Intron (SNP) | VAF 24/583 reads (4%) | called by muse, mutect2
- FHOD3 | c.1197-5368A>G | Intron (SNP) | VAF 14/398 reads (4%) | called by muse, mutect2
- HSPH1 | chr13:31162051 A>G | 5'Flank (SNP) | VAF 18/394 reads (5%) | called by muse, mutect2
- IKZF1 | c.161-8467G>A | Intron (SNP) | VAF 13/264 reads (5%) | catalogued as rs1346333173, COSV100497911; called by muse, mutect2
- KIAA2013 | c.1887+79C>T | Intron (SNP) | VAF 23/470 reads (5%) | catalogued as rs1223806149; called by muse, mutect2
- LENG8 | c.*1914C>T | 3'UTR (SNP) | VAF 22/536 reads (4%) | catalogued as rs1309088320; called by muse, mutect2
- MACF1 | c.15832-11561A>G | Intron (SNP) | VAF 12/361 reads (3%) | called by muse, mutect2
- MGAM | c.4618+13498C>T | Intron (SNP) | VAF 13/203 reads (6%) | called by muse, mutect2
- MSANTD1 | chr4:3261339 C>T | 3'Flank (SNP) | VAF 16/292 reads (5%) | catalogued as rs973390155; called by muse, mutect2
- NTRK3 | c.-138C>A | 5'UTR (SNP) | VAF 12/341 reads (4%) | called by muse, mutect2
- PBX1 | c.*2713C>T | 3'UTR (SNP) | VAF 16/297 reads (5%) | catalogued as rs1408115043; called by muse, mutect2
- PRG2 | c.*1G>A | 3'UTR (SNP) | VAF 14/242 reads (6%) | called by muse, mutect2
- PSMB10 | c.558+32G>A | Intron (SNP) | VAF 28/451 reads (6%) | called by muse, mutect2
- TIMM21 | c.462+848C>G | Intron (SNP) | VAF 15/289 reads (5%) | called by muse, mutect2
- TTN | c.10361-4116G>A | Intron (SNP) | VAF 16/274 reads (6%) | called by muse, mutect2
- USP2 | c.775-3720del | Intron (DEL) | VAF 10/103 reads (10%) | catalogued as rs972856893; called by mutect2, pindel
- XIRP1 | c.*1G>T | 3'UTR (SNP) | VAF 13/214 reads (6%) | called by muse, mutect2
